Somatic mutation profile of tumor specimen TCGA-AA-A022-01A (aliquot TCGA-AA-A022-01A-21D-A17O-10) from TCGA case TCGA-AA-A022, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage II; Age at diagnosis: 88.8 years (32,446 days).
Specimen TCGA-AA-A022-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c2daed2-870d-4d40-9e40-3b8d258629af.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-A022-11A (Solid Tissue Normal), aliquot TCGA-AA-A022-11A-11D-A17O-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6dd69231-e5c6-4a5b-8896-c83e574c5b7b

The open-access MAF lists 1,840 somatic variants for this specimen: 1,362 protein-altering or splice-affecting, 440 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 932, Silent 440, Frame Shift Del 274, Frame Shift Ins 61, Nonsense Mutation 51, Splice Site 22, RNA 15, Intron 14, In Frame Del 12, Splice Region 10, 3'UTR 3, 5'UTR 3.

Variants (750 of 1,840; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC6 | c.2974G>A p.G992R | Missense Mutation (SNP) | VAF 84/198 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs72657692, CM054640, COSV99228009; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AC068580.4 | c.268dup p.Q90Pfs*50 | Frame Shift Ins (INS) | VAF 13/50 reads (26%) | catalogued as rs752612332; ClinVar: pathogenic; called by mutect2, varscan2
- ALOX12B | c.1350del p.L451Sfs*16 | Frame Shift Del (DEL) | VAF 12/134 reads (9%) | catalogued as rs746723399, COSV59872823; ClinVar: pathogenic; called by mutect2, pindel
- ATP2A1 | c.2464dup p.R822Pfs*39 | Frame Shift Ins (INS) | VAF 28/106 reads (26%) | catalogued as rs751365374; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CYP1B1 | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs56010818, CM980503, COSV99307249; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- F5 | c.6304C>T p.R2102C | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs118203910, CM030037, COSV63121893; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1973G>A p.R658Q (on ENST00000281708 / NM_001349798.2; = p.R578Q on NM_018315.5) | Missense Mutation (SNP) | VAF 47/185 reads (25%) | hotspot (GDC flag); SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as rs759610249, COSV55905466; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- HNF1A | c.864del p.P291Qfs*51 | Frame Shift Del (DEL) | VAF 8/31 reads (26%) | catalogued as rs762703502, CM1412341, CX035684, COSV104379772; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KLHL3 | c.1480G>A p.A494T | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); catalogued as rs199469633, CM120723, COSV59050916; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.10653dup p.A3552Sfs*4 | Frame Shift Ins (INS) | VAF 48/120 reads (40%) | catalogued as rs763440821; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- MAGEL2 | c.1996del p.Q666Sfs*36 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | catalogued as rs770374710, CD1510958; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NLRP7 | c.2471+1G>A p.X824_splice (on ENST00000340844 / NM_206828.3; = p.X796_splice on NM_139176.3) | Splice Site (SNP) | VAF 81/199 reads (41%) | catalogued as rs104895505, CS061310, COSV60178990; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PCDH19 | c.1091del p.P364Rfs*4 | Frame Shift Del (DEL) | VAF 9/30 reads (30%) | catalogued as rs758946412, CD134966; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIGO | c.2361del p.T788Lfs*25 | Frame Shift Del (DEL) | VAF 20/81 reads (25%) | catalogued as rs770591449, COSV99956719; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- PIGO | c.2191del p.R731Vfs*17 | Frame Shift Del (DEL) | VAF 8/43 reads (19%) | catalogued as rs760848629; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PXDN | c.2568del p.C857Afs*5 | Frame Shift Del (DEL) | VAF 17/61 reads (28%) | catalogued as rs558163499, CD117085; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SCN1A | c.4339-1G>A p.X1447_splice (on ENST00000303395 / NM_001202435.3; = p.X1436_splice on NM_006920.6 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 20/284 reads (7%) | catalogued as rs1553522517, CS031804, COSV100319173, COSV100320730; ClinVar: pathogenic; called by muse, mutect2
- SCN5A | c.1273G>A p.A425T | Missense Mutation (SNP) | VAF 56/127 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.41); catalogued as rs761117662, COSV61118422; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- SF3B4 | c.1147del p.H383Mfs*75 | Frame Shift Del (DEL) | VAF 36/105 reads (34%) | catalogued as rs387907186, CD123383; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SLC16A1 | c.41del p.P14Qfs*10 | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | catalogued as rs606231309; ClinVar: pathogenic; called by mutect2, varscan2
- TRPS1 | c.2755G>A p.A919T (on ENST00000220888 / NM_001330599.2; = p.A932T on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/139 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057518972, CM010488, COSV99628169; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A4GALT | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.019); catalogued as rs750440854, COSV99966581; called by muse, varscan2
- AAAS | c.1547C>T p.P516L | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); catalogued as rs902369500, COSV99266801; called by muse, mutect2, varscan2
- AADACL2 | c.542C>T p.T181I | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.616); catalogued as rs764675842, COSV100735657; called by muse, mutect2
- AADACL2 | c.824G>T p.R275I | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.309); catalogued as COSV100735658; called by muse, mutect2, varscan2
- ABCA13 | c.3692T>C p.L1231P | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101329913; called by muse, mutect2, varscan2
- ABCA9 | c.3498del p.F1166Lfs*5 | Frame Shift Del (DEL) | VAF 43/153 reads (28%) | catalogued as rs1177267466; called by mutect2, pindel, varscan2
- ABCC4 | c.2689C>T p.R897W | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs769663620, COSV65317475; called by muse, mutect2, varscan2
- ABCC6 | c.4124T>C p.L1375P | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99228006; called by muse, mutect2, varscan2
- ABCD1 | c.2060C>T p.A687V | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV99497208; called by muse, mutect2
- ABHD12B | c.556C>T p.P186S (on ENST00000337334 / NM_001206673.2; = p.P109S on NM_181533.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as COSV100485535; called by muse, mutect2, varscan2
- ABL1 | c.2135G>A p.R712H | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.925); catalogued as rs766513552, COSV100583401; called by muse, mutect2, varscan2
- AC004922.1 | c.1228G>A p.V410M | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV53162608; called by muse, mutect2, varscan2
- ACKR3 | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as rs143911695; called by muse, varscan2
- ACMSD | c.310G>A p.V104I | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as rs372245923; called by muse, mutect2, varscan2
- ACOT12 | c.1147G>T p.E383* | Nonsense Mutation (SNP) | VAF 56/164 reads (34%) | catalogued as COSV100296706; called by muse, mutect2, varscan2
- ACSL1 | c.235G>A p.D79N | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as COSV99860312; called by muse, mutect2, varscan2
- ACSS2 | c.1666C>T p.R556W | Missense Mutation (SNP) | VAF 62/169 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774600970, COSV53626839; called by muse, mutect2, varscan2
- ACSS3 | c.1279C>T p.R427* | Nonsense Mutation (SNP) | VAF 27/117 reads (23%) | catalogued as rs774448807, COSV99698242; called by muse, mutect2, varscan2
- ACTA1 | c.136A>G p.M46V | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); catalogued as COSV100796698; called by muse, mutect2, varscan2
- ACTG2 | c.85del p.R29Gfs*16 | Frame Shift Del (DEL) | VAF 29/91 reads (32%) | catalogued as rs751325833; called by mutect2, pindel, varscan2
- ACTL10 | c.658C>T p.H220Y | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as COSV99864440; called by muse, varscan2
- ACTR1B | c.332C>T p.T111M | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780700382, COSV56705245; called by muse, mutect2, varscan2
- ACVR1B | c.1346A>T p.D449V | Missense Mutation (SNP) | VAF 90/178 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as COSV99231242; called by muse, mutect2, varscan2
- ADAMTS20 | c.4570C>T p.R1524* | Nonsense Mutation (SNP) | VAF 35/56 reads (63%) | catalogued as rs186549011, COSV101238834; called by muse, mutect2, varscan2
- ADAMTS5 | c.1211C>T p.A404V | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV53184176, COSV99536978; called by muse, mutect2, varscan2
- ADAMTSL5 | c.505G>T p.G169W | Missense Mutation (SNP) | VAF 100/268 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100389042; called by muse, mutect2, varscan2
- ADCY2 | c.2465G>T p.R822I | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.366); catalogued as COSV57903018; called by muse, mutect2, varscan2
- ADCY5 | c.3172C>T p.R1058C | Missense Mutation (SNP) | VAF 70/158 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as rs759519156, COSV59199318; called by muse, mutect2, varscan2
- ADGRA3 | c.3643G>A p.E1215K | Missense Mutation (SNP) | VAF 92/278 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1404660498, COSV99292871; called by muse, mutect2, varscan2
- ADGRG6 | c.1085C>T p.P362L | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.178); catalogued as rs184591267; called by muse, mutect2, varscan2
- ADIPOQ | c.455G>A p.C152Y | Missense Mutation (SNP) | VAF 64/200 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100292078; called by muse, mutect2, varscan2
- AGAP1 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 54/183 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1328244428, COSV58324497, COSV58333147; called by muse, mutect2, varscan2
- AGAP1 | c.2224G>A p.D742N (on ENST00000304032 / NM_001037131.3; = p.D689N on NM_014914.5) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.378); catalogued as rs954210067, COSV100363668; called by muse, mutect2, varscan2
- AGK | c.1132-1G>T p.X378_splice | Splice Site (SNP) | VAF 24/65 reads (37%) | catalogued as COSV100814521; called by muse, mutect2, varscan2
- AGO1 | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 65/200 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV64595103; called by muse, mutect2, varscan2
- AGO1 | c.2435G>A p.R812Q | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs867363147, COSV100940747; called by muse, mutect2
- AGO2 | c.1763A>G p.Q588R | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV99595182; called by mutect2, varscan2
- AGO3 | c.1864C>T p.H622Y | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.566); catalogued as COSV99867950; called by muse, mutect2
- AGTPBP1 | c.3237del p.K1079Nfs*10 (on ENST00000357081 / NM_001330701.2; = p.K1039Nfs*10 on NM_015239.2) | Frame Shift Del (DEL) | VAF 98/310 reads (32%) | catalogued as COSV61278568; called by mutect2, pindel, varscan2
- AHNAK | c.10831A>G p.S3611G | Missense Mutation (SNP) | VAF 47/151 reads (31%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.961); catalogued as rs773658459, COSV99945433; called by muse, mutect2, varscan2
- AIP | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 54/125 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as rs4930199, CM157188; ClinVar: benign; called by muse, mutect2, varscan2
- AK5 | c.1620+2C>T p.X540_splice (on ENST00000354567 / NM_174858.3; = p.X514_splice on NM_012093.4) | Splice Site (SNP) | VAF 54/156 reads (35%) | catalogued as rs770347979, COSV100642358; called by muse, varscan2
- AL358113.1 | c.3914G>A p.R1305H | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.121); catalogued as rs1037430967, COSV61957022; called by muse, mutect2, varscan2
- ALAS1 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs766975956, COSV100050196; called by muse, mutect2, varscan2
- ALDH1A1 | c.569T>A p.V190E | Missense Mutation (SNP) | VAF 64/108 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as COSV99920992; called by muse, mutect2, varscan2
- ALDH2 | c.414T>G p.D138E | Missense Mutation (SNP) | VAF 62/261 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.632); catalogued as COSV55669841; called by muse, mutect2, varscan2
- ALOX12B | c.1654G>T p.G552C | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1201448391, COSV100046611; called by muse, mutect2, varscan2
- AMIGO3 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as rs756633927, COSV100246421; called by muse, mutect2, varscan2
- AMOTL2 | c.2177G>T p.G726V (on ENST00000422605; = p.G727V on NM_016201.4) | Missense Mutation (SNP) | VAF 6/125 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); catalogued as COSV99850579; called by muse, mutect2
- AMPD2 | c.1202C>T p.T401M | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs751131036, COSV99857322; called by muse, mutect2, varscan2
- ANGPT2 | c.445-1G>T p.X149_splice | Splice Site (SNP) | VAF 38/108 reads (35%) | catalogued as COSV100290584; called by muse, mutect2, varscan2
- ANGPTL7 | c.280C>T p.R94W | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771394500, COSV63880241; called by muse, mutect2, varscan2
- ANK2 | c.5786C>T p.S1929L | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs779278730, COSV52173219, COSV52192251; called by muse, mutect2, varscan2
- ANKRD10 | c.808G>A p.V270I | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs755781873, COSV99941018; called by muse, mutect2, varscan2
- ANKRD27 | c.3086T>C p.V1029A | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV100042521; called by muse, mutect2, varscan2
- ANKRD35 | c.1826C>T p.A609V | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.354); catalogued as COSV100841622; called by muse, mutect2, varscan2
- ANKRD50 | c.1406C>T p.A469V | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs376403231, COSV72385179; called by muse, mutect2, varscan2
- ANO10 | c.790G>A p.G264S | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.014); catalogued as rs375470443; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AP1G2 | c.1345del p.A449Pfs*84 | Frame Shift Del (DEL) | VAF 39/134 reads (29%) | catalogued as rs749982998; called by mutect2, varscan2
- APC2 | c.3709G>A p.V1237M | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV99279113; called by muse, mutect2, varscan2
- APOB | c.9406C>T p.R3136C | Missense Mutation (SNP) | VAF 60/173 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as rs72653102; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APOB | c.5063G>T p.G1688V | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.967); catalogued as COSV99263404; called by muse, mutect2, varscan2
- ARC | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.649); catalogued as rs771620864, COSV100751650, COSV63078381; called by muse, varscan2
- ARFGEF3 | c.6001C>T p.R2001W | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs182084247, COSV99292209; called by muse, mutect2, varscan2
- ARHGAP32 | c.2105G>A p.R702H (on ENST00000310343 / NM_001378025.1; = p.R353H on NM_014715.4) | Missense Mutation (SNP) | VAF 56/153 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as rs149060649; called by muse, mutect2, varscan2
- ARHGAP39 | c.1095del p.S366Rfs*18 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | catalogued as rs751388541; called by mutect2, pindel*, varscan2
- ARHGAP45 | c.842del p.G281Afs*16 | Frame Shift Del (DEL) | VAF 23/89 reads (26%) | catalogued as COSV57429840; called by mutect2, pindel, varscan2
- ARHGAP9 | c.1414G>A p.A472T (on ENST00000393797 / NM_001319850.2; = p.A453T on NM_032496.4) | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.054); catalogued as COSV99953646; called by muse, mutect2, varscan2
- ARHGEF18 | c.1129G>T p.A377S (on ENST00000359920 / NM_001130955.2; = p.A273S on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.545); catalogued as rs756709811, COSV100148924; called by muse, mutect2, varscan2
- ARHGEF40 | c.2209del p.A737Pfs*3 | Frame Shift Del (DEL) | VAF 20/87 reads (23%) | catalogued as rs749402223; called by mutect2, pindel, varscan2
- ARHGEF7 | c.1966C>T p.R656W (on ENST00000375741 / NM_001113511.2; = p.R478W on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866152255, COSV54538783, COSV54548582; called by muse, mutect2, varscan2
- ARID3A | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV99708227; called by muse, mutect2, varscan2
- ARMC3 | c.1499C>T p.A500V | Missense Mutation (SNP) | VAF 99/267 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1364429442, COSV99957397; called by muse, mutect2, varscan2
- ARMCX2 | c.1309A>G p.I437V | Missense Mutation (SNP) | VAF 170/286 reads (59%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.891); catalogued as COSV100168013, COSV57530761; called by muse, mutect2, varscan2
- ASCC3 | c.6561G>T p.Q2187H | Missense Mutation (SNP) | VAF 69/165 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.371); catalogued as COSV100976193; called by muse, mutect2, varscan2
- ASPHD2 | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs747070863, COSV99313098, COSV99313499; called by muse, mutect2, varscan2
- ASXL2 | c.375G>T p.E125D | Missense Mutation (SNP) | VAF 20/305 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.053); catalogued as rs374285356, COSV99710118; called by muse, mutect2
- ATCAY | c.742G>T p.G248C | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV100008445, COSV56658323, COSV56659582; called by muse, mutect2, varscan2
- ATM | c.3070G>A p.A1024T | Missense Mutation (SNP) | VAF 53/178 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.13); catalogued as rs1397754737, COSV99587113; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP12A | c.437A>G p.Y146C | Missense Mutation (SNP) | VAF 65/169 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as COSV99516950; called by muse, mutect2, varscan2
- ATP13A1 | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99365562; called by muse, mutect2, varscan2
- ATP13A1 | c.1072C>T p.P358S | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99365565; called by muse, mutect2, varscan2
- ATP13A2 | c.68C>G p.T23R | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.193); catalogued as COSV100453879; called by muse, mutect2, varscan2
- ATP5F1D | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as rs781350269, COSV99289104; called by muse, mutect2, varscan2
- ATP7A | c.1789G>A p.V597M | Missense Mutation (SNP) | VAF 136/219 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781959472, COSV58451117; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATPSCKMT | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs559270054, COSV54726807, COSV99725982; called by muse, mutect2, varscan2
- ATRNL1 | c.1960G>A p.A654T | Missense Mutation (SNP) | VAF 51/212 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as COSV100744074; called by muse, mutect2, varscan2
- AVPR1A | c.752C>T p.T251M | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.875); catalogued as COSV100146795, COSV54546135; called by muse, mutect2, varscan2
- AXIN2 | c.2062del p.L688* | Frame Shift Del (DEL) | VAF 29/90 reads (32%) | catalogued as CM067349, COSV61056020; called by mutect2, pindel, varscan2
- B4GALT6 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 108/196 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs901456078, COSV52704419; called by muse, varscan2
- BAHCC1 | c.7213G>A p.E2405K | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as rs782256549, COSV100311100; called by muse, mutect2, varscan2
- BAZ2A | c.5413A>G p.I1805V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV51640895; called by muse, mutect2
- BCAS2 | c.309G>A p.W103* | Nonsense Mutation (SNP) | VAF 109/307 reads (36%) | catalogued as COSV101058482; called by muse, mutect2, varscan2
- BCOR | c.934C>T p.Q312* | Nonsense Mutation (SNP) | VAF 83/113 reads (73%) | catalogued as COSV60714969; called by muse, mutect2, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 34/70 reads (49%) | catalogued as rs768244116; called by mutect2, pindel, varscan2
- BEND3 | c.2326C>T p.R776W | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64680264; called by muse, mutect2, varscan2
- BEND3 | c.1507A>G p.S503G | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100944534; called by muse, mutect2, varscan2
- BICC1 | c.440T>C p.V147A | Missense Mutation (SNP) | VAF 54/163 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100874693; called by muse, mutect2, varscan2
- BICC1 | c.2101G>A p.A701T | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); catalogued as rs775676179, COSV54066020; called by muse, mutect2, varscan2
- BIRC2 | c.62T>C p.I21T | Missense Mutation (SNP) | VAF 68/215 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV99926503; called by muse, mutect2, varscan2
- BMX | c.215C>T p.T72M | Missense Mutation (SNP) | VAF 326/434 reads (75%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs774703027, COSV100564259, COSV100564556; called by mutect2, varscan2
- BNC1 | c.225del p.M76Cfs*14 | Frame Shift Del (DEL) | VAF 27/85 reads (32%) | catalogued as rs751941533; called by mutect2, pindel, varscan2
- BRAF | c.1328dup p.A444Cfs*9 (on ENST00000288602 / NM_001374244.1; = p.A404Cfs*9 on NM_004333.6 and 3 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 20/70 reads (29%) | catalogued as rs777474487; called by mutect2, varscan2
- BRINP1 | c.2048G>A p.G683D | Missense Mutation (SNP) | VAF 44/244 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as COSV99774317; called by muse, mutect2, varscan2
- BRINP1 | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 58/228 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99059353, COSV99774319; called by muse, mutect2, varscan2
- BRSK1 | c.1135dup p.R379Pfs*54 | Frame Shift Ins (INS) | VAF 17/54 reads (31%) | catalogued as rs746043904; called by mutect2, varscan2
- BRWD1 | c.6926del p.L2309* | Frame Shift Del (DEL) | VAF 21/133 reads (16%) | catalogued as rs1455506786, COSV59000653; called by mutect2, pindel, varscan2
- BSN | c.6919C>T p.R2307W | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs768774052, COSV99607149; called by muse, mutect2, varscan2
- BSX | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1466704692, COSV58006322; called by muse, mutect2, varscan2
- BTBD3 | c.1244C>G p.S415C | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54779135, COSV99655599; called by muse, mutect2, varscan2
- C11orf24 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs756449465, COSV100422461, COSV100422672; called by muse, mutect2, varscan2
- C15orf39 | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.027); catalogued as COSV100641178; called by muse, mutect2
- C15orf39 | c.1421del p.P474Qfs*91 | Frame Shift Del (DEL) | VAF 34/104 reads (33%) | catalogued as COSV62298237; called by mutect2, varscan2
- C16orf46 | c.743G>A p.C248Y | Missense Mutation (SNP) | VAF 111/366 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); catalogued as COSV100215082; called by muse, mutect2, varscan2
- C16orf78 | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV54556399; called by muse, mutect2, varscan2
- C16orf78 | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1252336191, COSV54555752; called by muse, mutect2, varscan2
- C17orf58 | c.131T>C p.I44T | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.249); catalogued as COSV100558699; called by muse, mutect2, varscan2
- C19orf57 | c.1942del p.L648Cfs*25 (on ENST00000586783 / NM_001345843.1; = p.L617Cfs*25 on NM_024323.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 22/64 reads (34%) | catalogued as rs1270763461; called by mutect2, pindel, varscan2
- C1orf159 | c.455C>T p.T152M (on ENST00000379339 / NM_001330306.2; = p.T116M on NM_017891.5) | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772422279, COSV99618119; called by muse, mutect2, varscan2
- C4orf50 | c.661C>T p.R221C (on ENST00000324058; = p.R1453C on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/184 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs201256752, COSV60689457; called by muse, mutect2, varscan2
- C8B | c.1629del p.I544Lfs*51 | Frame Shift Del (DEL) | VAF 18/55 reads (33%) | catalogued as rs762770227; called by mutect2, pindel, varscan2
- CA2 | c.440dup p.L147Ffs*7 | Frame Shift Ins (INS) | VAF 98/305 reads (32%) | catalogued as rs763603775; called by mutect2, varscan2
- CAAP1 | c.571A>T p.I191F | Missense Mutation (SNP) | VAF 130/318 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.165); catalogued as COSV61700397; called by mutect2, varscan2
- CABLES1 | c.938C>G p.S313* (on ENST00000256925 / NM_001100619.2; = p.S48* on NM_138375.2) | Nonsense Mutation (SNP) | VAF 53/96 reads (55%) | catalogued as COSV99908254; called by muse, mutect2, varscan2
- CABP2 | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 123/285 reads (43%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs768734103, COSV53708793; called by muse, mutect2, varscan2
- CACNA1A | c.3827G>A p.R1276Q | Missense Mutation (SNP) | VAF 64/155 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.782); catalogued as COSV64206552; called by muse, mutect2, varscan2
- CACNA1D | c.736C>T p.R246* | Nonsense Mutation (SNP) | VAF 15/60 reads (25%) | catalogued as COSV55438145; called by muse, mutect2, varscan2
- CACNA1D | c.4839G>T p.Q1613H (on ENST00000350061 / NM_001128840.3; = p.Q1633H on NM_000720.4) | Missense Mutation (SNP) | VAF 78/186 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99856507; called by muse, mutect2, varscan2
- CACNA1D | c.6205G>A p.E2069K (on ENST00000350061 / NM_001128840.3; = p.E2089K on NM_000720.4) | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.562); catalogued as rs373783390; called by muse, mutect2, varscan2
- CACNA1E | c.6346C>T p.R2116C (on ENST00000367573 / NM_001205293.3; = p.R2073C on NM_000721.4) | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as rs765523959, COSV62382695; called by muse, mutect2, varscan2
- CACNA1H | c.5023C>T p.R1675W | Missense Mutation (SNP) | VAF 140/445 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs760740366, COSV61993947; called by muse, varscan2
- CADM4 | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV55928525; called by muse, mutect2, varscan2
- CALCOCO1 | c.404G>T p.G135V | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.335); catalogued as COSV100017111; called by muse, mutect2, varscan2
- CAMK2G | c.403A>G p.R135G | Missense Mutation (SNP) | VAF 59/174 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99989404; called by muse, mutect2, varscan2
- CAMKK2 | c.1474C>T p.R492C | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs1451826262, COSV100242579; called by muse, mutect2, varscan2
- CAMSAP2 | c.4309del p.M1437* (on ENST00000236925 / NM_001297707.2; = p.M1426* on NM_203459.3) | Frame Shift Del (DEL) | VAF 38/118 reads (32%) | catalogued as rs1375954479; called by mutect2, varscan2
- CAMTA1 | c.1690G>A p.A564T | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0); catalogued as rs966383954, COSV100345986; called by muse, mutect2, varscan2
- CAMTA1 | c.2779G>T p.A927S | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV57922011; called by muse, mutect2, varscan2
- CAPN10 | c.571G>T p.A191S | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.186); catalogued as rs1280534206, COSV54377549, COSV99549918; called by muse, mutect2, varscan2
- CARNS1 | c.137del p.P46Rfs*28 | Frame Shift Del (DEL) | VAF 16/60 reads (27%) | catalogued as COSV57132090; called by mutect2, pindel, varscan2
- CASD1 | c.1626del p.A543Qfs*13 | Frame Shift Del (DEL) | VAF 50/154 reads (32%) | catalogued as rs770159446; called by mutect2, varscan2
- CASP8 | c.626C>T p.S209L (on ENST00000432109 / NM_033355.3; = p.S226L on NM_001228.4) | Missense Mutation (SNP) | VAF 131/362 reads (36%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs1351320412, COSV51849767; called by muse, varscan2
- CASP8 | c.701del p.G234Dfs*4 (on ENST00000432109 / NM_033355.3; = p.G251Dfs*4 on NM_001228.4) | Frame Shift Del (DEL) | VAF 74/247 reads (30%) | catalogued as COSV51844924; called by mutect2, pindel, varscan2
- CASP8AP2 | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs745563258, COSV99386732; called by muse, mutect2, varscan2
- CATSPER3 | c.867G>A p.M289I | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV99253885; called by muse, mutect2, varscan2
- CCDC17 | c.592G>A p.G198R | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.111); catalogued as rs774726919, COSV51971552; called by muse, mutect2, varscan2
- CCDC180 | c.4614del p.K1539Nfs*17 | Frame Shift Del (DEL) | VAF 20/75 reads (27%) | catalogued as rs1423532083; called by mutect2, pindel, varscan2
- CCDC57 | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as rs370460701; called by muse, mutect2, varscan2
- CCDC80 | c.790G>A p.G264S | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV99244198; called by muse, mutect2, varscan2
- CCDC80 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52814717; called by muse, mutect2, varscan2
- CCIN | c.1195C>T p.R399W | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.941); catalogued as rs142836285, COSV58725324; called by muse, mutect2, varscan2
- CCNA2 | c.818del p.P273Qfs*3 | Frame Shift Del (DEL) | VAF 31/111 reads (28%) | catalogued as rs1560632032; called by mutect2, pindel, varscan2
- CCR5 | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 44/143 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.473); catalogued as rs764278401, CM104770, COSV52751490; called by muse, mutect2, varscan2
- CCT6A | c.748del p.Y250Tfs*11 | Frame Shift Del (DEL) | VAF 42/98 reads (43%) | catalogued as COSV51905804; called by mutect2, varscan2
- CD163 | c.1142G>A p.R381H | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.059); catalogued as rs780185045, COSV63136816; called by muse, mutect2, varscan2
- CD22 | c.2129G>A p.R710Q | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as rs776104112, COSV50061342, COSV50061536; called by muse, mutect2, varscan2
- CD300LB | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100075286; called by muse, mutect2, varscan2
- CD34 | c.785del p.K262Sfs*6 | Frame Shift Del (DEL) | VAF 119/364 reads (33%) | catalogued as COSV60414017; called by mutect2, pindel, varscan2
- CD47 | c.942A>C p.K314N | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100790091; called by mutect2, varscan2
- CD7 | c.677C>T p.S226L | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs751672673, COSV100444756; called by muse, mutect2, varscan2
- CDADC1 | c.1373T>C p.M458T | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as COSV99212528; called by muse, mutect2, varscan2
- CDC42BPG | c.3076C>T p.R1026C | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); catalogued as rs769398599, COSV61348063; called by muse, mutect2, varscan2
- CDC45 | c.793G>A p.V265M | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.888); catalogued as rs551487753, COSV54247406; called by muse, mutect2, varscan2
- CDH16 | c.1444G>A p.A482T | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.152); catalogued as rs995411029, COSV100233629; called by muse, mutect2
- CDH23 | c.2565A>C p.K855N | Missense Mutation (SNP) | VAF 51/140 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0.152); catalogued as COSV99818663, COSV99824080; called by muse, mutect2, varscan2
- CDH4 | c.1232C>A p.A411E | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100848403; called by muse, mutect2, varscan2
- CDK11A | c.1687A>G p.I563V (on ENST00000378633 / NM_001313896.2; = p.I560V on NM_024011.4) | Missense Mutation (SNP) | VAF 55/369 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs768015274, COSV52307940; called by muse, mutect2, varscan2
- CDK20 | c.955del p.H319Tfs*16 (on ENST00000325303 / NM_001039803.3; = p.H298Tfs*16 on NM_012119.4) | Frame Shift Del (DEL) | VAF 41/222 reads (18%) | catalogued as rs749463697; called by mutect2, pindel, varscan2
- CDK3 | c.158C>T p.S53L | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs770199924, COSV100043911; called by muse, mutect2, varscan2
- CDK5RAP2 | c.4258C>T p.R1420W | Missense Mutation (SNP) | VAF 75/411 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs143596126, COSV100575047; called by muse, mutect2, varscan2
- CDKN2B | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52805270; called by muse, mutect2, varscan2
- CDON | c.3589G>A p.V1197I | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs911339564, COSV99700453; called by muse, mutect2, varscan2
- CDPF1 | c.41A>G p.E14G | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.174); catalogued as COSV99415097; called by muse, mutect2, varscan2
- CEACAM16 | c.1135C>T p.R379W | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771692758, COSV101312629; called by muse, mutect2, varscan2
- CELA3A | c.501C>T p.T167= | Splice Region (SNP) | VAF 26/79 reads (33%) | catalogued as COSV99266371; called by muse, mutect2, varscan2
- CELSR2 | c.3772T>G p.S1258A | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as rs760258795, COSV99602990; called by muse, mutect2, varscan2
- CEMIP | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs199948256, COSV99585974; called by muse, mutect2, varscan2
- CEMIP | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 69/199 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.324); catalogued as COSV99585977; called by muse, mutect2, varscan2
- CENPJ | c.3887A>C p.K1296T | Missense Mutation (SNP) | VAF 100/315 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99692058; called by muse, mutect2, varscan2
- CENPV | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.224); catalogued as COSV55333047; called by muse, mutect2, varscan2
- CEP112 | c.2810T>C p.L937P (on ENST00000392769 / NM_001353127.1; = p.L193P on NM_001037325.3) | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100438860; called by muse, mutect2, varscan2
- CEP170B | c.263G>A p.R88H (on ENST00000453495; = p.R18H on NM_015005.3) | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1247117233, COSV101371384; called by muse, mutect2, varscan2
- CEP70 | c.1055T>C p.L352P | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99388791; called by muse, mutect2, varscan2
- CES1 | c.561del p.N188Tfs*28 | Frame Shift Del (DEL) | VAF 17/83 reads (20%) | catalogued as COSV62086598; called by mutect2, pindel, varscan2
- CFAP251 | c.320T>C p.M107T | Missense Mutation (SNP) | VAF 64/299 reads (21%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV99945549; called by muse, varscan2
- CFAP251 | c.337C>T p.Q113* | Nonsense Mutation (SNP) | VAF 146/280 reads (52%) | catalogued as COSV99945551; called by muse, varscan2
- CFAP43 | c.3934C>T p.R1312C | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.721); catalogued as rs201811267; called by muse, mutect2, varscan2
- CFAP46 | c.7622C>T p.A2541V | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.062); catalogued as rs143790683, COSV54155598; called by muse, mutect2, varscan2
- CFAP65 | c.1319A>G p.Y440C | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99838223; called by muse, mutect2, varscan2
- CHAT | c.1253C>T p.A418V | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs376230019; called by muse, mutect2, varscan2
- CHD2 | c.297G>A p.M99I | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.885); catalogued as COSV59120523; called by muse, mutect2
- CHD2 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1041959719, COSV100560491; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHD2 | c.4044G>T p.K1348N | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.521); catalogued as COSV101244665; called by muse, mutect2
- CHD5 | c.3236G>A p.R1079Q | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV99312364; called by muse, mutect2, varscan2
- CHD5 | c.2282T>C p.I761T | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99312368; called by muse, mutect2, varscan2
- CHERP | c.2399C>A p.S800Y | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV99549962; called by muse, mutect2, varscan2
- CHMP2B | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99773205; called by muse, mutect2, varscan2
- CHODL | c.202C>A p.L68I | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV100166578; called by muse, mutect2, varscan2
- CHPF2 | c.1796C>A p.P599H | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV99222718; called by muse, mutect2, varscan2
- CHRDL2 | c.1007G>T p.G336V | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.101); catalogued as COSV99733517; called by muse, mutect2, varscan2
- CHRM2 | c.1334C>G p.A445G | Missense Mutation (SNP) | VAF 73/188 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.199); catalogued as COSV100280671, COSV100281046; called by muse, mutect2, varscan2
- CHST2 | c.1069C>T p.R357C | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100535824, COSV100535855, COSV58887289; called by muse, mutect2, varscan2
- CIC | c.3743del p.P1248Hfs*54 | Frame Shift Del (DEL) | VAF 15/55 reads (27%) | catalogued as COSV50671496; called by mutect2, pindel, varscan2
- CIITA | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs761597254, COSV60860278; called by muse, mutect2, varscan2
- CILK1 | c.1313G>A p.S438N (on ENST00000350082 / NM_001375397.1; = p.S431N on NM_014920.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as COSV100607471; called by muse, varscan2
- CILP | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs143279369; called by muse, mutect2, varscan2
- CIZ1 | c.497G>T p.G166V | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99476609; called by muse, mutect2, varscan2
- CLDN9 | c.110G>A p.G37D | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.46); catalogued as rs746271447, COSV100172032; called by muse, mutect2, varscan2
- CLDND1 | c.518C>T p.T173M | Missense Mutation (SNP) | VAF 71/227 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as rs748541120, COSV100360648; called by muse, mutect2, varscan2
- CLEC16A | c.1682C>T p.T561M | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs763777406, COSV101277797; called by muse, mutect2, varscan2
- CLK3 | c.805G>A p.A269T (on ENST00000395066 / NM_001130028.1; = p.A121T on NM_003992.4) | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.033); catalogued as rs148465298; called by muse, mutect2, varscan2
- CNGB1 | c.802C>A p.P268T | Missense Mutation (SNP) | VAF 55/134 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99201386; called by muse, mutect2, varscan2
- CNKSR1 | c.1679G>A p.R560H (on ENST00000374253 / NM_001297647.2; = p.R553H on NM_006314.3) | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs148602031; called by muse, mutect2, varscan2
- CNOT3 | c.1645C>T p.R549W | Missense Mutation (SNP) | VAF 54/145 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1420624033, COSV99651459; called by muse, mutect2, varscan2
- CNTNAP4 | c.1070T>C p.M357T | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs1350170549, COSV56693317; called by muse, mutect2, varscan2
- CNTNAP4 | c.2147C>T p.S716L | Missense Mutation (SNP) | VAF 103/297 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs571000371, COSV56664435; called by muse, mutect2, varscan2
- COBL | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372443929; called by muse, mutect2, varscan2
- COL11A1 | c.1339G>A p.A447T | Missense Mutation (SNP) | VAF 70/221 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.067); catalogued as COSV62190911; called by muse, mutect2, varscan2
- COL16A1 | c.1309C>T p.P437S | Missense Mutation (SNP) | VAF 119/297 reads (40%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV99593489; called by muse, mutect2, varscan2
- COL20A1 | c.1679dup p.R561Efs*168 | Frame Shift Ins (INS) | VAF 21/61 reads (34%) | catalogued as rs761988638; called by mutect2, varscan2
- COL3A1 | c.3100C>T p.R1034C | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1178112512, COSV58582183; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A6 | c.1441G>A p.A481T | Missense Mutation (SNP) | VAF 56/168 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as COSV100649759; called by muse, mutect2, varscan2
- COMMD5 | c.479A>G p.D160G | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV100295627; called by muse, mutect2, varscan2
- COQ8B | c.730G>T p.A244S | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV99699264; called by muse, mutect2, varscan2
- CORO1A | c.1102G>A p.A368T | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as rs1028173314, COSV99531796; called by muse, mutect2, varscan2
- CPAMD8 | c.5629G>A p.A1877T (on ENST00000651564; = p.A1830T on NM_015692.5) | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.011); catalogued as rs538315226, COSV99935052; called by muse, mutect2, varscan2
- CPNE1 | c.1501G>A p.V501M (on ENST00000352393; = p.V506M on NM_003915.5) | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.531); catalogued as rs143661266; called by muse, mutect2, varscan2
- CPSF1 | c.2926G>A p.A976T | Missense Mutation (SNP) | VAF 52/152 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.106); catalogued as rs782081187, COSV100450154; called by muse, mutect2, varscan2
- CPSF6 | c.1639G>A p.E547K | Missense Mutation (SNP) | VAF 167/606 reads (28%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.905); catalogued as COSV99878967; called by muse, mutect2, varscan2
- CPT1A | c.779T>G p.L260R | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99680539; called by muse, mutect2, varscan2
- CPXM1 | c.604A>G p.T202A | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.192); catalogued as COSV101013672; called by muse, mutect2, varscan2
- CRACD | c.1550G>A p.R517H | Missense Mutation (SNP) | VAF 70/175 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1365781651, COSV51714358, COSV99948491; called by muse, mutect2, varscan2
- CREB3L3 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs751875949, COSV50176737; called by muse, mutect2, varscan2
- CREBBP | c.6451C>T p.R2151W | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.824); catalogued as rs1361732490, COSV52115948; called by muse, mutect2
- CRNKL1 | c.2150A>G p.Q717R | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as COSV100131454; called by muse, mutect2, varscan2
- CROCC | c.5623C>T p.R1875C | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); catalogued as rs182106939; called by muse, mutect2
- CRYBG3 | c.6019C>A p.L2007I | Missense Mutation (SNP) | VAF 68/157 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99476572; called by mutect2, varscan2
- CRYGC | c.175C>T p.R59W | Missense Mutation (SNP) | VAF 55/155 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as rs1469741282, COSV56408965; called by muse, mutect2, varscan2
- CSDE1 | c.1669G>A p.E557K (on ENST00000358528 / NM_001007553.3; = p.E526K on NM_007158.6) | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as COSV54757893, COSV99793981; called by muse, mutect2, varscan2
- CSKMT | c.613C>T p.R205* | Nonsense Mutation (SNP) | VAF 30/70 reads (43%) | catalogued as rs778729080, COSV100648995; called by muse, mutect2, varscan2
- CSMD3 | c.10920del p.F3640Lfs*61 (on ENST00000297405 / NM_001363185.1; = p.F3471Lfs*61 on NM_052900.3) | Frame Shift Del (DEL) | VAF 15/88 reads (17%) | catalogued as rs766438669; called by mutect2, pindel, varscan2
- CSMD3 | c.1583G>A p.R528Q (on ENST00000297405 / NM_001363185.1; = p.R424Q on NM_052900.3) | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs779272178, COSV52147660, COSV52147973; called by muse, mutect2, varscan2
- CSNK1A1 | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 62/153 reads (41%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.182); catalogued as rs865943998, COSV55793928; called by muse, mutect2, varscan2
- CSNK1G3 | c.49C>T p.R17* | Nonsense Mutation (SNP) | VAF 104/258 reads (40%) | catalogued as COSV100631316; called by muse, mutect2, varscan2
- CTDSPL2 | c.155T>A p.I52N | Missense Mutation (SNP) | VAF 56/89 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99526499; called by muse, mutect2, varscan2
- CTSB | c.536G>A p.C179Y | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100565795; called by muse, mutect2, varscan2
- CTSV | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 68/195 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.538); catalogued as rs764260070, COSV99414293; called by muse, varscan2
- CTSV | c.906C>A p.S302R | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52345941; called by muse, varscan2
- CTTNBP2 | c.2573G>A p.S858N | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as COSV50457791, COSV99352928; called by muse, mutect2, varscan2
- CUBN | c.1688C>T p.A563V | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV64714418; called by muse, mutect2, varscan2
- CUX2 | c.3581C>T p.S1194L | Missense Mutation (SNP) | VAF 16/289 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55648204; called by muse, mutect2
- CYP1B1 | c.649G>A p.D217N | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.055); catalogued as COSV99572556; called by muse, mutect2, varscan2
- CYP26A1 | c.1353_1355del p.L452del | In Frame Del (DEL) | VAF 24/105 reads (23%) | catalogued as rs1362434045; called by pindel, varscan2
- CYP2A7 | c.724C>T p.Q242* | Nonsense Mutation (SNP) | VAF 103/176 reads (59%) | catalogued as COSV99393639; called by muse, mutect2, varscan2
- DACT1 | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.911); catalogued as COSV100241564; called by muse, mutect2, varscan2
- DAGLA | c.620C>T p.T207M | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.719); catalogued as rs536638905, COSV57198472; called by muse, mutect2, varscan2
- DBH | c.841G>A p.G281R | Missense Mutation (SNP) | VAF 26/274 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs747491059, COSV55040891; called by muse, mutect2
- DCAF4L2 | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 53/134 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1459776004, COSV60476643; called by muse, mutect2, varscan2
- DCHS1 | c.922G>A p.D308N | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.827); catalogued as rs763608227, COSV100201425; called by muse, mutect2, varscan2
- DDI2 | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV100197392; called by muse, mutect2, varscan2
- DDX27 | c.874G>A p.V292M | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs761573110, COSV100874636; called by muse, mutect2, varscan2
- DENND4B | c.3934C>T p.R1312C | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs754408493, COSV100768371; called by muse, mutect2, varscan2
- DENND5A | c.3388C>T p.R1130* | Nonsense Mutation (SNP) | VAF 13/28 reads (46%) | catalogued as rs1381160481, COSV60231569; called by muse, mutect2, varscan2
- DGAT2L6 | c.746T>C p.F249S | Missense Mutation (SNP) | VAF 39/156 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as COSV100283875; called by muse, mutect2, varscan2
- DGCR8 | c.1642A>G p.I548V | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); catalogued as COSV100707791; called by muse, mutect2, varscan2
- DGKD | c.2689G>A p.A897T (on ENST00000264057 / NM_152879.3; = p.A853T on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.615); catalogued as rs765978079, COSV51080025; called by muse, mutect2, varscan2
- DGKG | c.1357C>T p.R453W | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); catalogued as rs373512874; called by muse, mutect2, varscan2
- DHCR7 | c.1285C>T p.P429S | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100831691; called by muse, mutect2, varscan2
- DHRS2 | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs562008596, COSV99158709; called by muse, mutect2, varscan2
- DHX30 | c.3403G>A p.V1135M (on ENST00000445061 / NM_138615.3; = p.V1096M on NM_014966.3) | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.074); catalogued as rs753692624, COSV99274638; called by muse, mutect2, varscan2
- DIAPH2 | c.1532G>A p.R511Q | Missense Mutation (SNP) | VAF 263/414 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs201017046, COSV100230570; called by muse, mutect2, varscan2
- DIDO1 | c.5213del p.P1738Hfs*126 | Frame Shift Del (DEL) | VAF 21/53 reads (40%) | catalogued as COSV56631767; called by mutect2, varscan2
- DLG2 | c.1850C>T p.A617V | Missense Mutation (SNP) | VAF 57/258 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.333); catalogued as COSV99712430; called by muse, mutect2, varscan2
- DLG3 | c.1280G>A p.R427H (on ENST00000374360 / NM_021120.4; = p.R90H on NM_020730.3) | Missense Mutation (SNP) | VAF 59/181 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); catalogued as rs775293712, COSV52079852; called by muse, mutect2, varscan2
- DLGAP2 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760292969, COSV70098570; called by muse, mutect2
- DLK2 | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 57/151 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.325); catalogued as rs768837940, COSV99766569; called by muse, mutect2, varscan2
- DNAH10 | c.11775C>A p.S3925R (on ENST00000409039; = p.S3864R on NM_207437.3) | Missense Mutation (SNP) | VAF 120/215 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.287); catalogued as COSV101291920; called by muse, mutect2, varscan2
- DNAH12 | c.252+1G>C p.X84_splice | Splice Site (SNP) | VAF 77/211 reads (36%) | catalogued as COSV100244313; called by muse, mutect2, varscan2
- DNAH17 | c.2986G>C p.D996H | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as COSV67758939; called by muse, mutect2, varscan2
- DNAH2 | c.6296C>T p.A2099V | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.143); catalogued as rs1432599803, COSV101208976; called by muse, mutect2, varscan2
- DNAJC1 | c.975dup p.Q326Tfs*4 | Frame Shift Ins (INS) | VAF 107/403 reads (27%) | catalogued as rs1233931895; called by mutect2, pindel, varscan2
- DNM1L | c.1771G>T p.G591* (on ENST00000549701 / NM_012062.5; = p.G554* on NM_005690.4) | Nonsense Mutation (SNP) | VAF 105/401 reads (26%) | catalogued as COSV99845740; called by muse, mutect2, varscan2
- DOCK10 | c.280T>C p.S94P | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as COSV99287472; called by muse, mutect2, varscan2
- DOCK11 | c.364T>C p.F122L | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV99352791; called by muse, mutect2, varscan2
- DOCK2 | c.3767A>C p.E1256A | Missense Mutation (SNP) | VAF 51/146 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.095); catalogued as COSV99910125; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 56/158 reads (35%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOK7 | c.257C>A p.A86D | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as COSV100403119; called by muse, mutect2, varscan2
- DOP1A | c.2750A>G p.Q917R | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV99380858; called by muse, mutect2, varscan2
- DOP1B | c.2541dup p.G848Wfs*77 | Frame Shift Ins (INS) | VAF 18/114 reads (16%) | catalogued as rs750520568; called by mutect2, varscan2
- DOP1B | c.5636C>A p.A1879D | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0.102); catalogued as COSV101215011; called by muse, mutect2, varscan2
- DRAXIN | c.884C>T p.P295L | Missense Mutation (SNP) | VAF 84/265 reads (32%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.964); catalogued as rs775629878, COSV99610542; called by muse, mutect2, varscan2
- DST | c.6046G>A p.D2016N | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT tolerated (0.99); PolyPhen benign (0.003); catalogued as COSV99750670; called by muse, mutect2, varscan2
- DTNBP1 | c.779_781del p.G260del | In Frame Del (DEL) | VAF 24/78 reads (31%) | catalogued as rs760628074; called by pindel, varscan2
- DUSP6 | c.911C>T p.T304I | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV99683932; called by muse, mutect2, varscan2
- DVL2 | c.1324C>T p.R442C | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs865809670, COSV99138305; called by muse, mutect2, varscan2
- DYRK1A | c.2138G>A p.G713D | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV58709305; called by muse, mutect2, varscan2
- DYRK3 | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV65605481; called by muse, mutect2, varscan2
- DZANK1 | c.41T>C p.L14S | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV52755017; called by muse, mutect2, varscan2
- E4F1 | c.1390G>A p.A464T | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs926673319, COSV100065334, COSV57038558; called by muse, mutect2, varscan2
- ECHDC2 | c.677C>T p.A226V (on ENST00000371522 / NM_001198961.2; = p.A195V on NM_018281.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.243); catalogued as COSV100597431; called by muse, mutect2, varscan2
- ECM2 | c.30dup p.L11Sfs*8 | Frame Shift Ins (INS) | VAF 22/113 reads (19%) | catalogued as rs752987091; called by mutect2, varscan2
- ECPAS | c.1783A>G p.M595V | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.149); catalogued as COSV99397441; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2168C>T p.T723M | Missense Mutation (SNP) | VAF 57/167 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1231165786, COSV62569708; called by muse, mutect2, varscan2
- EFCAB7 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 68/225 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.02); catalogued as rs1383841396, COSV52133747; called by muse, mutect2, varscan2
- EIF3A | c.1405C>T p.R469W | Missense Mutation (SNP) | VAF 63/204 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770069171, COSV64961783; called by muse, mutect2, varscan2
- EIF4G3 | c.2948A>G p.N983S | Missense Mutation (SNP) | VAF 86/236 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.092); catalogued as rs767874521, COSV99943117; called by muse, mutect2, varscan2
- EIF5B | c.2686C>T p.P896S | Missense Mutation (SNP) | VAF 66/185 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1254050576, COSV99176783; called by muse, mutect2, varscan2
- ELF5 | c.343G>A p.G115S (on ENST00000312319 / NM_198381.2; = p.G105S on NM_001422.4) | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs778628535, COSV99141146; called by muse, mutect2, varscan2
- ELL | c.1556C>T p.S519L | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.64); PolyPhen benign (0.098); catalogued as rs574270231, COSV53211509; called by muse, mutect2, varscan2
- ELOVL5 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 64/191 reads (34%) | SIFT tolerated (0.97); PolyPhen benign (0.001); catalogued as rs766390073, COSV58651232; called by muse, mutect2, varscan2
- ELP2 | c.332A>G p.Y111C | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV100626718; called by muse, mutect2, varscan2
- EMILIN1 | c.151dup p.R51Pfs*23 | Frame Shift Ins (INS) | VAF 18/68 reads (26%) | catalogued as rs1445463863; called by mutect2, pindel, varscan2
- ENTPD4 | c.1798G>A p.A600T | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs556405061, COSV62268617; called by muse, mutect2, varscan2
- ENTPD6 | c.372del p.R125Efs*6 | Frame Shift Del (DEL) | VAF 4/19 reads (21%) | catalogued as rs769657862; called by pindel, varscan2
- ENTR1 | c.686C>T p.S229L (on ENST00000357365 / NM_001039707.2; = p.S206L on NM_006643.4) | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1353497880, COSV53743513; called by muse, mutect2, varscan2
- EPB41L1 | c.1453G>T p.E485* | Nonsense Mutation (SNP) | VAF 135/357 reads (38%) | catalogued as COSV99148861; called by muse, mutect2, varscan2
- EPB41L4B | c.1210C>T p.R404* | Nonsense Mutation (SNP) | VAF 84/456 reads (18%) | catalogued as rs377479255; called by muse, mutect2, varscan2
- EPHA2 | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as rs746422722, COSV100626011, COSV100626349; called by muse, varscan2
- EPHA3 | c.1938del p.E647Rfs*9 | Frame Shift Del (DEL) | VAF 21/74 reads (28%) | catalogued as rs1467832547; called by mutect2, pindel, varscan2
- EPHB6 | c.426C>A p.D142E | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV101235936; called by muse, varscan2
- EPHB6 | c.849dup p.R284Qfs*41 | Frame Shift Ins (INS) | VAF 20/54 reads (37%) | catalogued as rs145544148; called by mutect2, varscan2
- EPHB6 | c.1508A>G p.N503S | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV100844109; called by muse, varscan2
- EPS8 | c.1061C>T p.A354V | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1431122681, COSV99842604; called by muse, mutect2, varscan2
- EPYC | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 50/214 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1183549045, COSV53802508; called by muse, mutect2, varscan2
- ERBB3 | c.2693G>A p.G898D | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99915667; called by muse, mutect2
- ERCC6 | c.2338G>A p.V780I | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762128995, COSV63389649; called by muse, mutect2, varscan2
- ESR1 | c.1754C>T p.T585M | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.533); catalogued as rs141662120, COSV52794676; called by muse, mutect2, varscan2
- ESYT3 | c.2038G>A p.G680R | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.271); catalogued as rs372599591; called by muse, mutect2, varscan2
- EVL | c.560del p.P187Hfs*41 (on ENST00000402714 / NM_001330221.2; = p.P189Hfs*41 on NM_016337.3) | Frame Shift Del (DEL) | VAF 33/108 reads (31%) | catalogued as rs746606863; called by mutect2, varscan2
- EXO1 | c.1691C>T p.P564L | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs751493652, COSV100799600; called by muse, mutect2, varscan2
- F11R | c.137T>C p.V46A | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV99230734; called by muse, mutect2, varscan2
- F12 | c.130G>A p.G44R | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99499400; called by muse, mutect2, varscan2
- F5 | c.1976-2A>G p.X659_splice | Splice Site (SNP) | VAF 28/83 reads (34%) | catalogued as COSV63122920, COSV63124448; called by muse, mutect2, varscan2
- FADS2 | c.1178G>A p.R393Q | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV53901218, COSV99609175; called by muse, mutect2, varscan2
- FAH | c.838-2A>G p.X280_splice | Splice Site (SNP) | VAF 30/89 reads (34%) | catalogued as rs1387788860, CS026047, COSV99930014; called by muse, mutect2, varscan2
- FAIM2 | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.091); catalogued as rs145638550; called by muse, mutect2, varscan2
- FAM110D | c.461C>T p.T154M | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.885); catalogued as COSV100957614; called by muse, mutect2, varscan2
- FAM118B | c.174A>T p.Q58H | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.979); catalogued as COSV100796810; called by muse, mutect2, varscan2
- FAM151B | c.756del p.K252Nfs*48 | Frame Shift Del (DEL) | VAF 88/306 reads (29%) | catalogued as rs764889708; called by mutect2, varscan2
- FAM160B1 | c.1787G>A p.R596Q | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.531); catalogued as rs754122876, COSV65088772; called by muse, mutect2, varscan2
- FAM171A1 | c.2410A>G p.T804A | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100967992; called by muse, mutect2, varscan2
- FAM171A1 | c.1601G>A p.R534H | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.685); catalogued as rs776191844, COSV65314038, COSV65318372; called by muse, mutect2, varscan2
- FAM193A | c.2497del p.M833Wfs*23 | Frame Shift Del (DEL) | VAF 78/194 reads (40%) | catalogued as rs768952789; called by mutect2, varscan2
- FAM207A | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs1383652085, COSV99384206; called by mutect2, varscan2
- FAM222B | c.719dup p.N241Efs*27 | Frame Shift Ins (INS) | VAF 15/52 reads (29%) | catalogued as rs764940150; called by mutect2, varscan2
- FANCA | c.3962G>A p.R1321H | Missense Mutation (SNP) | VAF 45/139 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs374649848; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FANCM | c.5086A>G p.K1696E | Missense Mutation (SNP) | VAF 8/179 reads (4%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV99950390; called by muse, mutect2
- FARP2 | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 55/145 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1176974527, COSV99883813; called by muse, mutect2, varscan2
- FAT3 | c.803T>C p.V268A | Missense Mutation (SNP) | VAF 55/175 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.052); catalogued as COSV53151029; called by muse, mutect2, varscan2
- FAT3 | c.12490G>A p.V4164I | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.94); PolyPhen benign (0.024); catalogued as rs765324804, COSV53151072; called by muse, mutect2, varscan2
- FAT4 | c.583G>T p.G195C | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101271814, COSV67887318; called by muse, mutect2, varscan2
- FAT4 | c.14564T>C p.M4855T | Missense Mutation (SNP) | VAF 66/220 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV100627182; called by muse, mutect2, varscan2
- FBXL20 | c.262C>T p.R88* | Nonsense Mutation (SNP) | VAF 74/225 reads (33%) | catalogued as COSV99233699; called by muse, mutect2, varscan2
- FBXL4 | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 72/200 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1187735129, COSV100013833; called by muse, varscan2
- FBXO15 | c.925C>A p.L309M | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.091); catalogued as COSV99503008; called by muse, mutect2, varscan2
- FBXO9 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 137/382 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.099); catalogued as rs760965873, COSV99762225; called by muse, mutect2, varscan2
- FBXW4 | c.1564C>T p.R522C | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1418569736, COSV100489341; called by muse, mutect2, varscan2
- FCHO2 | c.1588C>T p.R530W | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs368140227; called by muse, mutect2, varscan2
- FCN1 | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 34/286 reads (12%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs372242075; called by muse, varscan2
- FCRL5 | c.1518G>C p.Q506H | Missense Mutation (SNP) | VAF 119/348 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV100708494; called by muse, mutect2, varscan2
- FCRLB | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as COSV100396070; called by muse, mutect2, varscan2
- FEN1 | c.733C>G p.R245G | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.433); catalogued as COSV99952766; called by muse, mutect2, varscan2
- FGD6 | c.989G>A p.C330Y | Missense Mutation (SNP) | VAF 63/226 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs746127225, COSV100676342; called by muse, mutect2, varscan2
- FIGNL1 | c.926del p.K309Sfs*16 | Frame Shift Del (DEL) | VAF 85/240 reads (35%) | catalogued as rs1216734611; called by mutect2, varscan2
- FKBP10 | c.299C>A p.T100N | Missense Mutation (SNP) | VAF 54/150 reads (36%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.871); catalogued as COSV100387715; called by muse, varscan2
- FKBP15 | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 74/169 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as rs760349713, COSV53037806; called by muse, mutect2, varscan2
- FKBPL | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 87/126 reads (69%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs1167063174, COSV100913532; called by muse, mutect2, varscan2
- FLG | c.9907G>A p.G3303R | Missense Mutation (SNP) | VAF 156/300 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs778135195, COSV64235820; called by muse, mutect2, varscan2
- FLG | c.4868G>A p.R1623Q | Missense Mutation (SNP) | VAF 118/438 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs201196640, COSV64247556; called by muse, mutect2, varscan2
- FLG | c.3989G>A p.G1330D | Missense Mutation (SNP) | VAF 138/498 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as rs752028692, COSV64236240; called by muse, varscan2
- FLNB | c.7559C>T p.A2520V | Missense Mutation (SNP) | VAF 53/217 reads (24%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.853); catalogued as COSV99911628; called by muse, mutect2, varscan2
- FN1 | c.7027G>T p.E2343* (on ENST00000359671 / NM_001365524.2; = p.E2312* on NM_002026.4) | Nonsense Mutation (SNP) | VAF 33/90 reads (37%) | catalogued as COSV100115804, COSV60549918; called by muse, mutect2, varscan2
- FOXD4 | c.1148C>T p.A383V | Missense Mutation (SNP) | VAF 56/143 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1231318195, COSV58702806; called by muse, mutect2, varscan2
- FOXN3 | c.287del p.P96Hfs*42 | Frame Shift Del (DEL) | VAF 23/54 reads (43%) | catalogued as rs760347049; called by mutect2, pindel, varscan2
- FOXP1 | c.59C>T p.S20L | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as rs1348187295, COSV59519444; called by muse, varscan2
- FREM1 | c.4891A>G p.T1631A | Missense Mutation (SNP) | VAF 28/310 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.024); catalogued as COSV101083716; called by muse, mutect2
- FRG2C | c.155G>A p.S52N | Missense Mutation (SNP) | VAF 45/444 reads (10%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.644); catalogued as rs1179297288; called by muse, mutect2, varscan2
- FRMD4A | c.3014del p.P1005Qfs*8 | Frame Shift Del (DEL) | VAF 18/56 reads (32%) | catalogued as rs752538869; called by mutect2, pindel, varscan2
- FRMPD1 | c.3795G>T p.E1265D | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.037); catalogued as rs201302424, COSV66701147; called by muse, mutect2, varscan2
- FRMPD2 | c.848C>A p.S283Y | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs1226210347, COSV100563469; called by muse, mutect2, varscan2
- FRY | c.4867del p.L1623Wfs*22 | Frame Shift Del (DEL) | VAF 44/120 reads (37%) | catalogued as COSV100968937, COSV66566354, COSV66574218; called by mutect2, pindel, varscan2
- FTHL17 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 52/180 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.679); catalogued as COSV63266742; called by muse, mutect2, varscan2
- FUT7 | c.122del p.P41Rfs*38 | Frame Shift Del (DEL) | VAF 82/198 reads (41%) | catalogued as COSV55807740; called by mutect2, pindel, varscan2
- FXN | c.221C>T p.T74M (on ENST00000377270; = p.T149M on NM_000144.5) | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs551991546, COSV101040031; called by muse, mutect2, varscan2
- FZD3 | c.1031T>C p.I344T | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV99527827; called by muse, mutect2, varscan2
- FZD4 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 156/407 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.485); catalogued as rs1334618792, COSV72294740; called by muse, mutect2, varscan2
- FZD9 | c.1022C>T p.A341V | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100750759; called by muse, mutect2, varscan2
- GABRG2 | c.71C>T p.T24M | Missense Mutation (SNP) | VAF 64/196 reads (33%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.04); catalogued as COSV100729499; called by muse, varscan2
- GABRG3 | c.922C>T p.P308S | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61521069; called by muse, mutect2, varscan2
- GALNT10 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 49/201 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV99768134; called by muse, mutect2, varscan2
- GALNT14 | c.959G>T p.G320V | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100204031; called by muse, mutect2, varscan2
- GALNT17 | c.805C>T p.R269C | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs781199608, COSV61153886, COSV61176768; called by muse, mutect2, varscan2
- GCFC2 | c.1739G>A p.S580N | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0.037); catalogued as rs1558736689, COSV100319336; called by muse, mutect2, varscan2
- GDF6 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as rs1467807484, COSV54623834; called by muse, mutect2, varscan2
- GET4 | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as rs759801442, COSV56256593; called by muse, mutect2, varscan2
- GJB1 | c.698C>T p.S233L | Missense Mutation (SNP) | VAF 37/52 reads (71%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs749796053, COSV62139879; called by muse, mutect2, varscan2
- GJB3 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 76/223 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs976148533, COSV64904436; called by muse, mutect2, varscan2
- GLI2 | c.215G>A p.R72K | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV100082244; called by muse, mutect2, varscan2
- GLI3 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 103/301 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs749940791, COSV101229712; called by muse, mutect2, varscan2
- GLRA3 | c.22C>T p.R8W | Missense Mutation (SNP) | VAF 56/170 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.919); catalogued as COSV99926893; called by muse, mutect2, varscan2
- GMPS | c.613A>C p.N205H | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV99902858; called by muse, mutect2, varscan2
- GNL2 | c.1868G>T p.R623I | Missense Mutation (SNP) | VAF 128/389 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99953458; called by muse, mutect2, varscan2
- GNPDA2 | c.282del p.F94Lfs*6 | Frame Shift Del (DEL) | VAF 25/103 reads (24%) | catalogued as rs1489322870; called by mutect2, pindel, varscan2
- GPBP1 | c.361G>A p.G121R | Missense Mutation (SNP) | VAF 214/576 reads (37%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as COSV53310371; called by muse, mutect2, varscan2
- GPD1 | c.343G>T p.G115C | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99993710; called by muse, mutect2, varscan2
- GPD1 | c.364del p.X122_splice | Splice Site (DEL) | VAF 31/84 reads (37%) | catalogued as rs1224277565, CS120252; called by mutect2, pindel, varscan2
- GPHB5 | c.22C>A p.L8I | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.076); catalogued as COSV100030140; called by muse, mutect2, varscan2
- GPI | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs748408705, COSV62893793; called by muse, mutect2, varscan2
- GPR101 | c.314C>T p.T105M | Missense Mutation (SNP) | VAF 109/160 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV53238534, COSV99981240; called by muse, mutect2, varscan2
- GPR12 | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101197935; called by muse, mutect2, varscan2
- GPR149 | c.1636G>A p.A546T | Missense Mutation (SNP) | VAF 44/176 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as rs1200638787, COSV101078089; called by muse, mutect2, varscan2
- GPR173 | c.1012A>G p.I338V | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.1); catalogued as rs782095276, COSV100212010; called by muse, mutect2, varscan2
- GPR20 | c.436G>A p.V146M | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs758617428, COSV66684045; called by muse, mutect2, varscan2
- GPR50 | c.577G>A p.V193I | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.08); PolyPhen benign (0.443); catalogued as rs768655839, COSV54442018; called by muse, mutect2, varscan2
- GPR78 | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 71/186 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs368485565; called by muse, mutect2, varscan2
- GPSM2 | c.1420C>T p.R474* | Nonsense Mutation (SNP) | VAF 62/175 reads (35%) | catalogued as rs776770855, COSV51441866; called by muse, mutect2, varscan2
- GPT | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs776157825, COSV52954002; called by muse, varscan2
- GRIK2 | c.2546del p.N849Tfs*14 | Frame Shift Del (DEL) | VAF 18/59 reads (31%) | catalogued as rs760757380; called by mutect2, varscan2
- GRIK4 | c.1729C>T p.H577Y | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); catalogued as COSV101483419; called by muse, mutect2, varscan2
- GRIK4 | c.1943G>A p.R648H | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757609162, COSV101483420; called by muse, mutect2
- GRIN2B | c.3562G>A p.G1188S | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.006); catalogued as rs367543149, COSV101662898; ClinVar: not provided; called by muse, mutect2, varscan2
- GRIP2 | c.1585C>T p.H529Y (on ENST00000619221; = p.H432Y on NM_001080423.4) | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.897); catalogued as COSV99816899; called by muse, mutect2, varscan2
- GRM1 | c.1240A>G p.I414V | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); catalogued as COSV99263804; called by muse, mutect2, varscan2
- GRM6 | c.2323G>A p.V775M | Missense Mutation (SNP) | VAF 82/260 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs760164627, COSV51436761; called by muse, mutect2, varscan2
- GSDME | c.314del p.G105Afs*5 | Frame Shift Del (DEL) | VAF 28/98 reads (29%) | catalogued as rs755613828; called by mutect2, pindel, varscan2
- GSS | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.125); catalogued as rs780544238, COSV53811444; called by muse, mutect2, varscan2
- GTF2IRD2 | c.355T>C p.Y119H | Missense Mutation (SNP) | VAF 32/248 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1422871321; called by muse, mutect2, varscan2
- GTF3C2 | c.2665T>C p.F889L | Missense Mutation (SNP) | VAF 83/220 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs1345499152, COSV99272115; called by muse, mutect2, varscan2
- H3C13 | c.381G>T p.L127F | Missense Mutation (SNP) | VAF 116/410 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100516024; called by muse, mutect2, varscan2
- HACD3 | c.1061A>G p.Y354C | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV99970912; called by muse, mutect2
- HAL | c.1702C>T p.R568C | Missense Mutation (SNP) | VAF 35/183 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs765722855, COSV54117815; called by muse, mutect2, varscan2
- HBS1L | c.585del p.G196Dfs*40 | Frame Shift Del (DEL) | VAF 72/285 reads (25%) | catalogued as rs1412060705; called by mutect2, pindel, varscan2
- HCK | c.9dup p.R4_?3 | Frame Shift Ins (INS) | VAF 18/72 reads (25%) | catalogued as rs755024531; called by mutect2, varscan2
- HCN1 | c.2003A>G p.Y668C | Missense Mutation (SNP) | VAF 65/184 reads (35%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.887); catalogued as COSV100298366; called by muse, mutect2, varscan2
- HCN1 | c.1171G>T p.G391C | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57520200, COSV57522009; called by muse, mutect2, varscan2
- HCRTR1 | c.972C>A p.F324L | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as COSV65483901, COSV65484067; called by muse, mutect2, varscan2
- HDAC4 | c.2989-1G>T p.X997_splice | Splice Site (SNP) | VAF 25/78 reads (32%) | catalogued as COSV100612617; called by muse, mutect2, varscan2
- HDAC4 | c.590G>A p.S197N | Missense Mutation (SNP) | VAF 20/248 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV100612618; called by muse, mutect2
- HECA | c.1004del p.G335Dfs*27 | Frame Shift Del (DEL) | VAF 10/29 reads (34%) | catalogued as rs771658394; called by mutect2, pindel, varscan2
- HECW1 | c.3815G>A p.R1272Q | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs367661051, COSV67824610; called by muse, mutect2, varscan2
- HELZ | c.2716C>T p.R906* | Nonsense Mutation (SNP) | VAF 29/91 reads (32%) | catalogued as rs1312644072, COSV100698488; called by muse, mutect2, varscan2
- HERC2 | c.11100G>T p.W3700C | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99870679; called by muse, mutect2, varscan2
- HIF3A | c.784G>A p.A262T (on ENST00000377670 / NM_152795.4; = p.A193T on NM_022462.4) | Missense Mutation (SNP) | VAF 68/187 reads (36%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.815); catalogued as COSV52199600; called by muse, mutect2, varscan2
- HJV | c.644C>T p.T215I (on ENST00000336751 / NM_213653.4; = p.T102I on NM_145277.5) | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100382186; called by muse, mutect2, varscan2
- HK3 | c.2537C>T p.A846V | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99457766; called by muse, mutect2, varscan2
- HLCS | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746588785, COSV100357815; called by muse, varscan2
- HLX | c.947C>T p.T316M | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as COSV65045727; called by muse, mutect2, varscan2
- HMGXB4 | c.1754A>G p.Q585R | Missense Mutation (SNP) | VAF 79/209 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.115); catalogued as COSV99329893; called by muse, mutect2, varscan2
- HNRNPC | c.829del p.D277Mfs*6 (on ENST00000420743; = p.D264Mfs*6 on NM_004500.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 61/192 reads (32%) | catalogued as rs1566590411, COSV100193248; called by mutect2, pindel, varscan2
- HNRNPF | c.528A>G p.I176M | Missense Mutation (SNP) | VAF 89/207 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.734); catalogued as COSV100562954; called by muse, mutect2, varscan2
- HNRNPL | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.375); catalogued as rs1228792246, COSV55492313; called by muse, varscan2
- HOOK2 | c.1231C>T p.R411W | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751125633, COSV99317301; called by muse, mutect2, varscan2
- HYDIN | c.7694G>T p.G2565V | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59270227, COSV99991871; called by muse, mutect2, varscan2
- HYDIN | c.6440G>A p.R2147H | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs558300717, COSV99991659; called by muse, mutect2, varscan2
- IARS1 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 45/228 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as COSV100986772; called by muse, mutect2, varscan2
- IBA57 | c.847C>T p.R283W | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs951345105, COSV100812748; called by muse, mutect2, varscan2
- ICAM5 | c.1621C>T p.R541C | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.636); catalogued as rs1414106315, COSV55747257; called by muse, mutect2
- IDE | c.1706del p.L569Cfs*45 | Frame Shift Del (DEL) | VAF 25/65 reads (38%) | catalogued as rs771790236; called by mutect2, varscan2
- IDH2 | c.992C>T p.T331M | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1472715809, COSV99184073; called by muse, mutect2, varscan2
- IDI1 | c.76G>T p.A26S | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.009); catalogued as rs989626920, COSV100830136; called by muse, mutect2, varscan2
- IFFO1 | c.1089del p.R364Gfs*47 (on ENST00000396840 / NM_001330324.2; = p.R367Gfs*47 on NM_080730.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 21/82 reads (26%) | catalogued as rs750779916, COSV60737300; called by mutect2, pindel, varscan2
- IFNLR1 | c.1535G>A p.R512Q | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0.059); catalogued as rs764742091, COSV100551961; called by muse, mutect2, varscan2
- IFT140 | c.2425C>T p.R809C | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs755748472, COSV99559675; called by muse, mutect2, varscan2
- IFT172 | c.3386C>T p.A1129V | Missense Mutation (SNP) | VAF 59/180 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1558367670, COSV99561710; called by muse, mutect2, varscan2
- IGF1R | c.322G>A p.G108S | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51317159; called by muse, mutect2, varscan2
- IGKV1-5 | c.256G>A p.G86S | Missense Mutation (SNP) | VAF 98/303 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as rs764059454; called by muse, mutect2, varscan2
- IGSF1 | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.992); catalogued as COSV63838663; called by muse, mutect2
- IL17RA | c.811C>T p.R271C | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.169); catalogued as COSV100082847; called by muse, mutect2, varscan2
- IL17RB | c.1177G>A p.V393I | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs749453165, COSV99213537; called by muse, mutect2, varscan2
- IL18RAP | c.87del p.K29Nfs*66 | Frame Shift Del (DEL) | VAF 40/132 reads (30%) | catalogued as rs756319084; called by mutect2, pindel, varscan2
- IL1RL1 | c.581T>C p.V194A | Missense Mutation (SNP) | VAF 126/376 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs770476261, COSV99293554; called by muse, mutect2, varscan2
- ILF3 | c.1355C>T p.T452M | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370373655; called by muse, mutect2, varscan2
- IMPG1 | c.281A>G p.Q94R | Missense Mutation (SNP) | VAF 97/354 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.168); catalogued as COSV100885933; called by muse, mutect2, varscan2
- INPP5J | c.2752C>T p.R918C (on ENST00000331075 / NM_001284285.2; = p.R550C on NM_001002837.2) | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.65); catalogued as rs988380601, COSV99311286; called by muse, mutect2
- INSRR | c.2757del p.L920Cfs*37 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | catalogued as rs772259106; called by mutect2, pindel, varscan2
- INSRR | c.1252G>A p.D418N | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); catalogued as COSV100947093; called by muse, mutect2, varscan2
- IPMK | c.1144C>T p.R382* | Nonsense Mutation (SNP) | VAF 34/137 reads (25%) | catalogued as COSV64243565; called by muse, mutect2, varscan2
- IPMK | c.319C>T p.R107* | Nonsense Mutation (SNP) | VAF 16/64 reads (25%) | catalogued as rs758099009, COSV100880207; called by mutect2, varscan2
- IPO4 | c.2038G>A p.V680M | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs369678433; called by muse, mutect2, varscan2
- IPO9 | c.487G>A p.V163I | Missense Mutation (SNP) | VAF 53/174 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.233); catalogued as rs757892876, COSV100843317; called by muse, mutect2, varscan2
- IQSEC3 | c.1819G>A p.A607T (on ENST00000538872 / NM_001170738.2; = p.A304T on NM_015232.1) | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.49); catalogued as rs752727349, COSV100406787; called by muse, mutect2, varscan2
- IRF5 | c.611dup p.G205Wfs*12 | Frame Shift Ins (INS) | VAF 18/50 reads (36%) | catalogued as rs34686870; called by mutect2, pindel, varscan2
- IRF9 | c.1162G>A p.A388T | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs1290580672, COSV100138029; called by muse, mutect2, varscan2
- IRS1 | c.1791dup p.H598Afs*13 | Frame Shift Ins (INS) | VAF 18/55 reads (33%) | catalogued as rs761880048; called by mutect2, varscan2
- IRS4 | c.1614G>T p.Q538H | Missense Mutation (SNP) | VAF 44/71 reads (62%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); catalogued as COSV100929411; called by muse, mutect2, varscan2
- ISLR2 | c.1919G>A p.R640H | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV100679371; called by muse, mutect2, varscan2
- ITPK1 | c.187G>A p.V63I | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.17); catalogued as rs757596570, COSV50900004; called by muse, mutect2, varscan2
- ITPRIP | c.787G>A p.G263R | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs776290130, COSV99532381, COSV99532416; called by muse, mutect2, varscan2
- ITSN2 | c.1274G>A p.R425H | Missense Mutation (SNP) | VAF 138/368 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs777801668, COSV100742610; called by muse, mutect2, varscan2
- IZUMO1 | c.475T>C p.C159R | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99710453; called by muse, mutect2, varscan2
- JAK3 | c.3133C>A p.P1045T | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as COSV101512873; called by muse, mutect2, varscan2
- JAK3 | c.2159G>A p.S720N | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.038); catalogued as COSV101512874; called by muse, mutect2, varscan2
- JMY | c.857_858del p.C286Lfs*29 | Frame Shift Del (DEL) | VAF 32/124 reads (26%) | catalogued as rs1291650256; called by pindel, varscan2
- JPH3 | c.1094G>A p.R365H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.177); catalogued as rs375201712; called by muse, mutect2
- JTB | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0.038); catalogued as rs778131192, COSV99665590; called by muse, mutect2, varscan2
- JUP | c.938A>G p.Q313R | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.086); catalogued as COSV100159306; called by muse, mutect2, varscan2
- KALRN | c.1393A>G p.T465A | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.992); catalogued as COSV99561987; called by muse, mutect2, varscan2
- KBTBD4 | c.1214C>G p.T405R | Missense Mutation (SNP) | VAF 21/365 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV100442811; called by muse, mutect2
- KCNA4 | c.663del p.F221Lfs*21 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | catalogued as rs754892524; called by mutect2, pindel, varscan2
- KCNB1 | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65569037; called by muse, mutect2, varscan2
- KCNC3 | c.2197dup p.Q733Pfs*5 | Frame Shift Ins (INS) | VAF 8/25 reads (32%) | catalogued as rs765382637; called by mutect2, varscan2
- KCND1 | c.681C>A p.F227L | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV99501688; called by muse, mutect2, varscan2
- KCND2 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.048); catalogued as rs756823168, COSV58586030; called by muse, mutect2, varscan2
- KCNE4 | c.397del p.E133Rfs*3 | Frame Shift Del (DEL) | VAF 21/60 reads (35%) | catalogued as rs760505003; called by mutect2, pindel, varscan2
- KCNG4 | c.1544C>A p.P515H | Missense Mutation (SNP) | VAF 11/145 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.688); catalogued as COSV100376893; called by muse, mutect2
- KCNJ3 | c.848T>G p.L283R | Missense Mutation (SNP) | VAF 57/171 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99715184, COSV99715296; called by muse, mutect2, varscan2
- KCNJ5 | c.397C>A p.L133I | Missense Mutation (SNP) | VAF 176/534 reads (33%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.79); catalogued as COSV100610537; called by muse, mutect2, varscan2
- KCNT1 | c.184C>A p.L62M | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.861); catalogued as COSV100042637; called by muse, mutect2, varscan2
- KCTD19 | c.2301dup p.V768Rfs*12 | Frame Shift Ins (INS) | VAF 50/186 reads (27%) | catalogued as rs759860142; called by mutect2, varscan2
- KCTD3 | c.1910C>T p.T637I | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.021); catalogued as rs1558248637, COSV99378767; called by muse, mutect2, varscan2
- KDM2A | c.3170G>A p.R1057H | Missense Mutation (SNP) | VAF 53/129 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100445373; called by muse, mutect2, varscan2
- KDM4C | c.658C>T p.R220* | Nonsense Mutation (SNP) | VAF 81/530 reads (15%) | catalogued as rs779861232, COSV67190140; called by muse, mutect2, varscan2
- KDR | c.2359C>T p.R787W | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1139774, COSV55763897; called by muse, mutect2, varscan2
- KIAA0753 | c.1914del p.K638Nfs*18 | Frame Shift Del (DEL) | VAF 76/277 reads (27%) | catalogued as COSV63817190; called by mutect2, pindel, varscan2
- KIAA1549 | c.5276del p.P1759Rfs*66 | Frame Shift Del (DEL) | VAF 20/54 reads (37%) | catalogued as COSV54318123; called by mutect2, pindel, varscan2
- KIAA1958 | c.1344G>T p.K448N | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV100515814; called by muse, mutect2, varscan2
- KIF1C | c.2944A>G p.K982E | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.187); catalogued as rs1348637296, COSV100296939; called by muse, varscan2
- KIF21B | c.4161-1G>T p.X1387_splice (on ENST00000422435 / NM_001252100.2; = p.X1374_splice on NM_017596.4) | Splice Site (SNP) | VAF 3/52 reads (6%) | catalogued as COSV100143522; called by muse, mutect2
- KIF24 | c.1633G>T p.E545* | Nonsense Mutation (SNP) | VAF 121/222 reads (55%) | catalogued as rs765069486, COSV100799096; called by muse, mutect2, varscan2
- KIF3C | c.299G>A p.G100D | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99267011; called by muse, mutect2, varscan2
- KIF5B | c.2668C>T p.R890C | Missense Mutation (SNP) | VAF 104/380 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs760268366, COSV100191333; called by muse, mutect2, varscan2
- KIFAP3 | c.2341C>T p.R781C | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs766097860, COSV100846691; called by muse, mutect2, varscan2
- KIRREL3 | c.2174C>T p.T725M | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.719); catalogued as rs374832017; called by muse, mutect2, varscan2
- KLHL42 | c.1194del p.C399Vfs*44 | Frame Shift Del (DEL) | VAF 34/78 reads (44%) | catalogued as rs749194179; called by mutect2, pindel, varscan2
- KMT2C | c.13488del p.F4496Lfs*21 | Frame Shift Del (DEL) | VAF 12/99 reads (12%) | catalogued as COSV51456416; called by mutect2, pindel, varscan2
- KMT2D | c.9305del p.P3102Lfs*17 | Frame Shift Del (DEL) | VAF 18/82 reads (22%) | catalogued as COSV99040252, COSV99983483; called by mutect2, pindel, varscan2
- KPNA4 | c.1000C>T p.L334F | Missense Mutation (SNP) | VAF 103/297 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100514962; called by muse, mutect2, varscan2
- KRT31 | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as rs748743219, COSV52435034; called by muse, mutect2, varscan2
- KRTAP4-12 | c.161T>C p.V54A | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as COSV101224245; called by muse, mutect2, varscan2
- KSR1 | c.652G>T p.A218S (on ENST00000644974 / NM_001367810.1; = p.A81S on NM_014238.2) | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.48); PolyPhen benign (0.009); catalogued as COSV99257912; called by muse, mutect2, varscan2
- LACTB2 | c.309dup p.L104Tfs*28 | Frame Shift Ins (INS) | VAF 44/171 reads (26%) | catalogued as rs773915769; called by mutect2, pindel, varscan2
- LAG3 | c.512-1G>A p.X171_splice | Splice Site (SNP) | VAF 23/39 reads (59%) | catalogued as COSV99179875; called by muse, mutect2, varscan2
- LAMA1 | c.6842C>A p.S2281Y | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV101054880; called by muse, mutect2, varscan2
- LAMA1 | c.2263G>A p.G755S | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1266955784, COSV67543328; called by muse, mutect2, varscan2
- LAMA3 | c.7594G>A p.D2532N (on ENST00000313654 / NM_198129.4; = p.D923N on NM_000227.6) | Missense Mutation (SNP) | VAF 62/261 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99333881; called by muse, mutect2, varscan2
- LAMB3 | c.3157C>T p.Q1053* | Nonsense Mutation (SNP) | VAF 29/68 reads (43%) | catalogued as COSV99151629; called by muse, mutect2, varscan2
- LARGE1 | c.460G>A p.V154I | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.166); catalogued as rs138938225; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LETM1 | c.562G>A p.G188S | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.705); catalogued as rs1433033198, COSV100245174; called by muse, mutect2, varscan2
- LGI2 | c.1313G>T p.R438L | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101180740, COSV66122851; called by muse, mutect2, varscan2
- LHX2 | c.670C>T p.R224W | Missense Mutation (SNP) | VAF 63/139 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101010020; called by muse, mutect2, varscan2
- LIG1 | c.1502T>C p.M501T | Missense Mutation (SNP) | VAF 61/199 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV99618453; called by muse, mutect2, varscan2
- LIMS2 | c.718_720del p.K240del (on ENST00000355119 / NM_001161403.3; = p.K264del on NM_017980.4) | In Frame Del (DEL) | VAF 24/86 reads (28%) | catalogued as rs1348506135; called by pindel, varscan2
- LINGO4 | c.1397A>G p.D466G | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.131); catalogued as COSV100764922; called by muse, varscan2
- LOX | c.19G>A p.V7M | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV99140589; called by muse, mutect2, varscan2
- LRCH4 | c.223C>T p.L75= | Splice Region (SNP) | VAF 5/29 reads (17%) | catalogued as COSV53828352; called by muse, mutect2, varscan2
- LRFN2 | c.1744G>A p.A582T | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs771240052, COSV57832901; called by muse, mutect2, varscan2
- LRP1 | c.11968G>A p.E3990K | Missense Mutation (SNP) | VAF 61/216 reads (28%) | SIFT tolerated (0.77); PolyPhen benign (0.13); catalogued as rs773851515, COSV99674286; called by muse, mutect2, varscan2
- LRRC17 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 55/142 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs752823104, COSV50866456, COSV99978183; called by muse, mutect2, varscan2
- LRRC31 | c.668C>A p.P223H | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.901); catalogued as COSV99246289, COSV99246560; called by muse, mutect2, varscan2
- LRRC42 | c.236_237del p.E79Gfs*26 | Frame Shift Del (DEL) | VAF 45/141 reads (32%) | catalogued as rs1210520853; called by pindel, varscan2
- LRRC74A | c.1232A>C p.N411T | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as COSV99372158; called by muse, mutect2, varscan2
- LRRC8A | c.931G>A p.A311T | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (1); PolyPhen possibly damaging (0.48); catalogued as COSV99396222; called by muse, mutect2, varscan2
- LRRK1 | c.3304G>A p.E1102K | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV99437175, COSV99437437; called by muse, mutect2, varscan2
- LRRK2 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.181); catalogued as rs281865040, CM074927, COSV54164473; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRRK2 | c.6332_6335del p.I2111Nfs*4 | Frame Shift Del (DEL) | VAF 50/274 reads (18%) | catalogued as rs747108466; called by pindel, varscan2
- LRRTM1 | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99701699; called by muse, mutect2, varscan2
- LSM3 | c.118C>T p.R40* | Nonsense Mutation (SNP) | VAF 66/228 reads (29%) | catalogued as rs748145947, COSV53203904; called by muse, mutect2, varscan2
- LSM5 | c.142+1G>A p.X48_splice | Splice Site (SNP) | VAF 106/340 reads (31%) | catalogued as COSV56167640; called by muse, mutect2, varscan2
- LSMEM1 | c.38T>A p.I13N | Missense Mutation (SNP) | VAF 67/186 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as COSV100456203; called by muse, mutect2, varscan2
- LTF | c.908C>T p.P303L | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs200379115, COSV99206757; called by muse, mutect2, varscan2
- LUM | c.511C>A p.L171M | Missense Mutation (SNP) | VAF 48/174 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99898874; called by muse, mutect2, varscan2
- LUZP1 | c.2810dup p.T938Nfs*5 | Frame Shift Ins (INS) | VAF 44/194 reads (23%) | catalogued as COSV56503887; called by mutect2, pindel, varscan2
- LVRN | c.1516-1G>T p.X506_splice | Splice Site (SNP) | VAF 64/213 reads (30%) | catalogued as COSV100773313, COSV63497106; called by muse, mutect2, varscan2
- LY6G5B | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT tolerated (0.06); PolyPhen benign (0.171); catalogued as rs1286896800, COSV101020802; called by muse, mutect2, varscan2
- LYL1 | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV99316987; called by muse, mutect2, varscan2
- LYL1 | c.26A>T p.E9V | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.601); catalogued as COSV99316990; called by muse, mutect2, varscan2
- MACC1 | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs535198484, COSV100255314; called by muse, mutect2, varscan2
- MACIR | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1554237627, COSV60635576; called by muse, mutect2, varscan2
- MADCAM1 | c.1055A>G p.D352G | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as COSV99298287; called by muse, mutect2, varscan2
- MADD | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV100210972; called by muse, mutect2
- MAF | c.842T>G p.V281G | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV100391618; called by muse, mutect2, varscan2
- MAGEC2 | c.1087A>G p.S363G | Missense Mutation (SNP) | VAF 80/128 reads (63%) | SIFT tolerated (0.19); PolyPhen benign (0.066); catalogued as COSV99909375; called by muse, mutect2, varscan2
- MAGEE1 | c.1186G>A p.A396T | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV100819249; called by muse, mutect2
- MAP3K11 | c.2317C>T p.R773C | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.719); catalogued as rs763537644, COSV58419890; called by muse, mutect2, varscan2
- MAP4K1 | c.2218C>T p.R740W | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as rs1484809303, COSV67710737; called by muse, mutect2, varscan2
- MAPK11 | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.108); catalogued as rs1213569489, COSV53135521; called by muse, mutect2, varscan2
- MAPK8IP1 | c.974C>T p.P325L | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as rs774929831, COSV99571079; called by muse, mutect2, varscan2
- MAPKAP1 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 46/200 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.354); catalogued as rs1008519449, COSV99784316; called by muse, mutect2, varscan2
- MAST3 | c.1594G>A p.A532T | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as rs748960066, COSV53227635, COSV99444309; called by muse, mutect2
- MAST3 | c.2674C>T p.R892C | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs1178040525, COSV99444313; called by muse, mutect2
- MATK | c.265G>A p.V89I (on ENST00000310132 / NM_139355.3; = p.V90I on NM_002378.4) | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs774774723, COSV100035808, COSV59556653; called by muse, mutect2, varscan2
- MCCC1 | c.1570G>A p.D524N | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs200031275, COSV99659328; called by muse, mutect2, varscan2
- MCL1 | c.74G>A p.S25N | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.023); catalogued as COSV100329406, COSV100329764; called by muse, mutect2, varscan2
- MCOLN3 | c.260T>C p.V87A | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.634); catalogued as rs1188765626, COSV100352557; called by muse, mutect2, varscan2
- MDN1 | c.7057A>G p.S2353G | Missense Mutation (SNP) | VAF 13/135 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV101020731; called by muse, mutect2
- MDN1 | c.2015C>A p.P672H | Missense Mutation (SNP) | VAF 46/131 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101020732; called by muse, mutect2, varscan2
- MDN1 | c.1904G>A p.R635Q | Missense Mutation (SNP) | VAF 87/251 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as rs775308932, COSV65517211; called by muse, mutect2, varscan2
- MEGF8 | c.1610G>A p.R537H | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.965); catalogued as rs926015247, COSV52075537; called by muse, mutect2, varscan2
- MEGF8 | c.7247G>A p.R2416H (on ENST00000251268 / NM_001271938.2; = p.R2349H on NM_001410.3) | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); catalogued as rs756370726, COSV52095274; called by muse, mutect2, varscan2
- MEIS2 | c.793G>T p.G265C (on ENST00000561208 / NM_170675.5; = p.G252C on NM_002399.3) | Missense Mutation (SNP) | VAF 117/215 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99575702; called by muse, varscan2
- MFSD5 | c.1222A>G p.M408V | Missense Mutation (SNP) | VAF 164/310 reads (53%) | SIFT tolerated (0.39); PolyPhen benign (0.023); catalogued as rs371060411; called by muse, mutect2, varscan2
- MGA | c.7303C>T p.R2435W (on ENST00000219905 / NM_001164273.1; = p.R2226W on NM_001080541.2) | Missense Mutation (SNP) | VAF 126/215 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs779811318, COSV54947919; called by muse, mutect2, varscan2
- MGAT5B | c.1001del p.T334Kfs*4 | Frame Shift Del (DEL) | VAF 11/54 reads (20%) | catalogued as COSV56933715; called by mutect2, pindel, varscan2
- MGRN1 | c.142del p.H48Tfs*13 | Frame Shift Del (DEL) | VAF 61/216 reads (28%) | catalogued as COSV52148537; called by pindel, varscan2
- MGST1 | c.405del p.F135Lfs*15 | Frame Shift Del (DEL) | VAF 118/507 reads (23%) | catalogued as rs778971425; called by mutect2, varscan2
- MICAL1 | c.1150G>A p.A384T | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1258399774, COSV100668410; called by muse, mutect2, varscan2
- MICALL1 | c.1799C>T p.A600V | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs897655503, COSV99316989; called by muse, mutect2, varscan2
- MIEF2 | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0.253); catalogued as rs1170073251, COSV100493393, COSV100493444; called by muse, mutect2, varscan2
- MIEF2 | c.1229G>A p.G410D | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.073); catalogued as COSV100544037; called by muse, mutect2
- MIER3 | c.302T>C p.M101T | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as COSV100423506; called by muse, mutect2, varscan2
- MINDY4 | c.1157G>A p.R386K | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs905893541, COSV99518111; called by muse, mutect2, varscan2
- MIPEP | c.1357C>A p.R453S | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as COSV101193004; called by muse, mutect2, varscan2
- MLF1 | c.746C>G p.S249* | Nonsense Mutation (SNP) | VAF 27/312 reads (9%) | catalogued as COSV100575939; called by muse, mutect2
- MLNR | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.045); catalogued as rs1403449104, COSV54534451; called by muse, mutect2, varscan2
- MMP15 | c.373C>A p.L125M | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.601); catalogued as COSV99539236; called by muse, mutect2, varscan2
- MMP25 | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs200558581; called by muse, mutect2, varscan2
- MORC1 | c.1331-2del p.X444_splice | Splice Site (DEL) | VAF 4/32 reads (13%) | catalogued as rs758380552, COSV99227961; called by pindel, varscan2
- MORC2 | c.1813-3del | Splice Region (DEL) | VAF 36/95 reads (38%) | catalogued as rs777649506, COSV53202254; called by mutect2, varscan2
- MOS | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as COSV100322712; called by muse, mutect2, varscan2
- MPI | c.23C>A p.P8Q | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as COSV100086206; called by muse, mutect2, varscan2
- MR1 | c.689del p.P230Qfs*5 | Frame Shift Del (DEL) | VAF 32/171 reads (19%) | catalogued as rs1254492579; called by mutect2, pindel, varscan2
- MRGPRD | c.131G>A p.G44D | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100482921; called by muse, mutect2, varscan2
- MROH2B | c.1367C>A p.T456N | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.964); catalogued as rs746281100, COSV68186680; called by muse, mutect2, varscan2
- MRPL50 | c.392A>G p.N131S | Missense Mutation (SNP) | VAF 66/300 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100879785; called by muse, mutect2
- MRPS9 | c.511A>G p.N171D | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV99305852; called by muse, mutect2, varscan2
- MSH5 | c.1352G>A p.R451H | Missense Mutation (SNP) | VAF 105/141 reads (74%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs139002853; called by muse, mutect2, varscan2
- MSL1 | c.800G>A p.R267Q (on ENST00000398532 / NM_001365919.1; = p.R4Q on NM_001012241.2) | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs1367096563, COSV100278004; called by muse, mutect2, varscan2
- MSX2 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1201449653, COSV53327472; called by muse, mutect2, varscan2
- MTG1 | c.561G>A p.M187I | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as COSV100448664; called by muse, mutect2, varscan2
- MVK | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 93/174 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV99949853; called by muse, mutect2, varscan2
- MYCBP2 | c.6940G>T p.A2314S (on ENST00000357337; = p.A2352S on NM_015057.5) | Missense Mutation (SNP) | VAF 53/155 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV62031727; called by muse, mutect2, varscan2
- MYCBPAP | c.1093G>A p.D365N | Missense Mutation (SNP) | VAF 81/249 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.15); catalogued as COSV100087612; called by muse, mutect2, varscan2
- MYH3 | c.208del p.L70Wfs*11 | Frame Shift Del (DEL) | VAF 12/55 reads (22%) | catalogued as COSV56863477; called by mutect2, pindel, varscan2
- MYO10 | c.4870G>A p.G1624S | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.674); catalogued as COSV57016812; called by muse, mutect2, varscan2
- MYO1F | c.1780C>T p.R594* | Nonsense Mutation (SNP) | VAF 60/157 reads (38%) | catalogued as rs754747494, COSV100596326, COSV100596670; called by muse, mutect2, varscan2
- MYO7A | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs373942326; called by muse, mutect2, varscan2
- MYORG | c.2035G>A p.A679T | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.616); catalogued as COSV52626861; called by muse, mutect2
- MYOT | c.225G>T p.Q75H | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.57); catalogued as COSV99524716; called by muse, mutect2, varscan2
- MZB1 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as rs374843946; called by muse, mutect2, varscan2
- NAA16 | c.499G>T p.A167S | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV101038216; called by muse, mutect2, varscan2
- NALCN | c.1144C>T p.R382W | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs867467226, COSV51959339; called by muse, mutect2, varscan2
- NALCN | c.884G>A p.R295H | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as rs377716963, COSV51938533; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NANOS2 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.94); catalogued as COSV100379449; called by muse, mutect2, varscan2
- NAP1L3 | c.515G>A p.S172N | Missense Mutation (SNP) | VAF 82/139 reads (59%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.902); catalogued as COSV100220139; called by muse, mutect2, varscan2
- NAV2 | c.6744C>A p.H2248Q (on ENST00000396087 / NM_001244963.2; = p.H2189Q on NM_145117.5) | Missense Mutation (SNP) | VAF 55/169 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV100216037; called by muse, mutect2, varscan2
- NBEAL1 | c.5426G>A p.R1809H | Missense Mutation (SNP) | VAF 66/152 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs372102920; called by muse, varscan2
- NCAPD2 | c.2508del p.F837Sfs*36 | Frame Shift Del (DEL) | VAF 50/107 reads (47%) | catalogued as rs772347389; called by mutect2, pindel, varscan2
- NCOA3 | c.1835C>A p.P612H | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0.01); catalogued as COSV100507081, COSV59066442; called by muse, mutect2, varscan2
- NCSTN | c.1285C>T p.R429* | Nonsense Mutation (SNP) | VAF 35/90 reads (39%) | catalogued as rs771414318, COSV99666682; called by muse, mutect2, varscan2
- NDST2 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.052); catalogued as rs748197644, COSV100013608; called by muse, mutect2, varscan2
- NDUFAF4 | c.386T>C p.F129S | Missense Mutation (SNP) | VAF 67/199 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV100293992; called by muse, mutect2, varscan2
- NECAB2 | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs748924576, COSV100533818; called by muse, mutect2, varscan2
- NECTIN1 | c.1114G>A p.G372S | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.105); catalogued as rs759345182, COSV99871744; called by muse, mutect2
- NEFM | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.342); catalogued as rs376739149, COSV55330735, COSV99646922; called by muse, mutect2, varscan2
- NEXMIF | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 99/171 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.322); catalogued as COSV99279516; called by muse, mutect2, varscan2
- NFATC3 | c.335A>G p.Q112R | Missense Mutation (SNP) | VAF 53/123 reads (43%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.966); catalogued as COSV100284834; called by muse, mutect2, varscan2
- NFIA | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.992); catalogued as rs1252714201, COSV100963174; called by muse, mutect2, varscan2
- NFIC | c.1268C>T p.P423L | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.577); catalogued as rs771779620, COSV100545038; called by muse, mutect2, varscan2
- NIBAN2 | c.421+2T>C p.X141_splice | Splice Site (SNP) | VAF 43/220 reads (20%) | catalogued as COSV100964845; called by muse, mutect2, varscan2
- NID1 | c.3121A>G p.N1041D | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.102); catalogued as COSV99936929; called by muse, mutect2, varscan2
- NINJ1 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 35/193 reads (18%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.532); catalogued as rs755546683, COSV100966592; called by muse, mutect2, varscan2
- NKAIN3 | c.116G>A p.G39E | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV60682031, COSV60691994; called by muse, varscan2
- NKPD1 | c.2102T>C p.L701P | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100521444; called by muse, mutect2, varscan2
- NKX3-1 | c.619C>T p.R207W | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs753524833, COSV66513039; called by muse, mutect2, varscan2
- NKX3-2 | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 120/282 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.976); catalogued as rs754533227, COSV101219830; called by muse, mutect2, varscan2
- NME7 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 65/153 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as rs755169173, COSV100890869; called by muse, mutect2, varscan2
- NMT1 | c.188del p.K63Rfs*17 | Frame Shift Del (DEL) | VAF 54/196 reads (28%) | catalogued as rs1567865446; called by mutect2, pindel, varscan2
- NOC3L | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 55/173 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs763109129, COSV64929629; called by muse, mutect2, varscan2
- NOD1 | c.2348G>A p.C783Y | Missense Mutation (SNP) | VAF 79/258 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs773339280, COSV99767763; called by muse, mutect2, varscan2
- NOD1 | c.276A>C p.Q92H | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV99767764; called by muse, mutect2, varscan2
- NOS1AP | c.700A>G p.S234G | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100722800; called by muse, mutect2, varscan2
- NOS2 | c.2827G>A p.V943I | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.426); catalogued as rs753799387, COSV100569471; called by muse, mutect2, varscan2
- NOS3 | c.1319del p.G440Afs*64 | Frame Shift Del (DEL) | VAF 19/77 reads (25%) | catalogued as rs749517498, COSV52496454; called by mutect2, pindel, varscan2
- NOSIP | c.394A>C p.K132Q | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.24); PolyPhen benign (0.154); catalogued as COSV100182103; called by muse, mutect2, varscan2
- NOTCH1 | c.5561G>A p.R1854H | Missense Mutation (SNP) | VAF 82/160 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs878855028, COSV53066047; ClinVar: uncertain significance; called by muse, varscan2
- NOTCH2 | c.5537A>G p.D1846G | Missense Mutation (SNP) | VAF 63/181 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.161); catalogued as COSV99862632; called by muse, mutect2, varscan2
- NOVA1 | c.101del p.P34Lfs*19 | Frame Shift Del (DEL) | VAF 26/56 reads (46%) | catalogued as rs765756993; called by mutect2, varscan2
- NPAS3 | c.43C>T p.R15* | Nonsense Mutation (SNP) | VAF 35/108 reads (32%) | catalogued as COSV100385944; called by muse, varscan2
- NPAS4 | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.718); catalogued as rs777027579, COSV60650844; called by muse, mutect2, varscan2
- NPBWR1 | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs146840260, COSV58697900; called by muse, mutect2, varscan2
- NPHP3 | c.1432G>A p.G478S | Missense Mutation (SNP) | VAF 57/210 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.833); catalogued as COSV100446593; called by muse, mutect2, varscan2
- NRDC | c.1847T>A p.I616N | Missense Mutation (SNP) | VAF 30/348 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100703049; called by muse, mutect2
- NRXN1 | c.1939T>G p.L647V | Missense Mutation (SNP) | VAF 67/196 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.952); catalogued as COSV58477011; called by muse, mutect2, varscan2
- NSD2 | c.1697C>T p.T566M | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV100372804; called by muse, mutect2, varscan2
- NTHL1 | c.788G>A p.R263H (on ENST00000219066; = p.R255H on NM_002528.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/184 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756036462, COSV99526089; called by muse, mutect2, varscan2
- NTRK3 | c.2032C>T p.R678* | Nonsense Mutation (SNP) | VAF 37/97 reads (38%) | catalogued as rs1419472052, COSV62305329, COSV62313231; called by muse, mutect2, varscan2
- NUAK1 | c.1096C>T p.R366W | Missense Mutation (SNP) | VAF 100/197 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs941006183, COSV54605720; called by muse, mutect2, varscan2
- NUFIP1 | c.1423C>T p.R475W | Missense Mutation (SNP) | VAF 70/227 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371806496; called by muse, mutect2, varscan2
- NUP160 | c.4096C>T p.H1366Y | Missense Mutation (SNP) | VAF 50/157 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs1322460209, COSV101021258; called by muse, mutect2, varscan2
- NUTM2G | c.712A>G p.I238V | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); catalogued as COSV100672554; called by mutect2, varscan2
- OBSCN | c.13447A>G p.T4483A | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.057); catalogued as rs1456599707, COSV99472073; called by muse, mutect2, varscan2
- OBSCN | c.20957C>T p.P6986L | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100800910; called by muse, mutect2
- OGFOD3 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746705584, COSV57340805; called by muse, mutect2, varscan2
- OLFM1 | c.180G>A p.W60* (on ENST00000371793 / NM_001282611.2; = p.W42* on NM_006334.4) | Nonsense Mutation (SNP) | VAF 18/70 reads (26%) | catalogued as COSV99423071; called by muse, mutect2, varscan2
- OPRM1 | c.1075A>G p.N359D | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100000305; called by muse, mutect2, varscan2
- OR10A2 | c.721T>C p.S241P | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as rs768034593, COSV100224924; called by muse, mutect2, varscan2
- OR13C3 | c.413G>A p.G138E | Missense Mutation (SNP) | VAF 47/317 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101053248; called by muse, mutect2, varscan2
- OR1E1 | c.413C>A p.P138H | Missense Mutation (SNP) | VAF 61/191 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.063); catalogued as COSV100491877; called by muse, mutect2, varscan2
- OR2A42 | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 34/100 reads (34%) | catalogued as rs778163355; called by mutect2, varscan2
- OR2H2 | c.320C>T p.T107I | Missense Mutation (SNP) | VAF 66/181 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV100589415; called by muse, mutect2, varscan2
- OR2L3 | c.379T>C p.F127L | Missense Mutation (SNP) | VAF 68/158 reads (43%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.529); catalogued as COSV100741905; called by muse, mutect2, varscan2
- OR2M3 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 140/396 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs138010167; called by muse, mutect2, varscan2
- OR2M7 | c.742G>C p.V248L | Missense Mutation (SNP) | VAF 86/284 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100522407, COSV58738519; called by muse, mutect2, varscan2
- OR51V1 | c.136T>C p.C46R | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.936); catalogued as COSV100343173; called by muse, mutect2, varscan2
- OR52J3 | c.933del p.K311Nfs*? | Frame Shift Del (DEL) | VAF 7/49 reads (14%) | catalogued as rs1254479213; called by mutect2, pindel, varscan2
- OR52K1 | c.139C>A p.L47I | Missense Mutation (SNP) | VAF 57/151 reads (38%) | SIFT tolerated (1); PolyPhen probably damaging (0.99); catalogued as COSV100297564; called by muse, mutect2, varscan2
- OR56A1 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 50/159 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as COSV100360387; called by muse, mutect2, varscan2
- OR5B12 | c.597del p.F199Lfs*13 | Frame Shift Del (DEL) | VAF 35/82 reads (43%) | catalogued as rs747074822; called by mutect2, varscan2
- OR6K2 | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as rs752799224, COSV100656655, COSV62744312; called by muse, mutect2, varscan2
- OR6K3 | c.554G>A p.C185Y (on ENST00000368146; = p.C169Y on NM_001005327.2) | Missense Mutation (SNP) | VAF 60/155 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1322601769, COSV100933826; called by muse, mutect2, varscan2
- OR8K1 | c.261G>A p.M87I | Missense Mutation (SNP) | VAF 78/211 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.275); catalogued as rs1350964624, COSV99687048; called by muse, mutect2, varscan2
- OS9 | c.950A>T p.E317V | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.634); catalogued as COSV99232490; called by muse, mutect2, varscan2
- OSBPL3 | c.733G>A p.V245I | Missense Mutation (SNP) | VAF 49/167 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.013); catalogued as rs150182562, COSV100513649; called by muse, mutect2, varscan2
- OSCP1 | c.895T>A p.L299M (on ENST00000356637 / NM_001330493.1; = p.L289M on NM_145047.5) | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99347000; called by muse, mutect2, varscan2
- OSMR | c.1849del p.T617Qfs*20 | Frame Shift Del (DEL) | VAF 30/78 reads (38%) | catalogued as rs762315064; called by mutect2, pindel, varscan2
- OTOL1 | c.120G>A p.M40I | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1163712798, COSV100019728; called by muse, varscan2
- OXCT2 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 74/215 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV59594352; called by muse, mutect2, varscan2
- P2RX2 | c.661G>A p.G221R (on ENST00000343948 / NM_170683.4; = p.G149R on NM_012226.5) | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as COSV57683158; called by muse, mutect2, varscan2
- PABPC5 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 82/116 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100442091; called by muse, mutect2, varscan2
- PACS2 | c.1811G>A p.R604H | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs782813839, COSV100330587; called by muse, mutect2, varscan2
- PADI6 | c.1829C>T p.A610V | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as rs749241013, COSV100639888; called by muse, mutect2, varscan2
- PAIP1 | c.658C>A p.R220S | Missense Mutation (SNP) | VAF 66/238 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100166482, COSV59085936; called by muse, varscan2
- PAK1 | c.772C>T p.R258* | Nonsense Mutation (SNP) | VAF 91/248 reads (37%) | catalogued as rs201726311, COSV53695751; called by muse, mutect2, varscan2
- PANK4 | c.2182C>T p.R728C | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750810615, COSV99615475; called by muse, mutect2, varscan2
- PARD3 | c.123T>C p.D41= | Splice Region (SNP) | VAF 37/97 reads (38%) | catalogued as COSV100400159; called by muse, mutect2, varscan2
- PARD3B | c.1655C>T p.A552V | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100592060; called by muse, mutect2, varscan2
- PARP6 | c.128A>G p.D43G | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99535739; called by muse, mutect2, varscan2
- PASK | c.962G>C p.S321T | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.138); catalogued as COSV52153143, COSV99298585; called by muse, mutect2, varscan2
- PASK | c.784G>A p.G262R | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372015883, COSV99298588; called by muse, mutect2, varscan2
- PCDH17 | c.2822C>T p.T941I | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.899); catalogued as rs1263085822, COSV100931406; called by muse, mutect2
- PCDH17 | c.3190C>A p.L1064M | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.445); catalogued as COSV100931407; called by muse, mutect2, varscan2
- PCDH19 | c.3191C>A p.P1064H (on ENST00000373034 / NM_001184880.2; = p.P1016H on NM_020766.3) | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99718948; called by muse, mutect2, varscan2
- PCDHA13 | c.1928C>T p.P643L | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.01); catalogued as COSV56510869; called by muse, mutect2
- PCDHA9 | c.94C>A p.H32N | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.672); catalogued as COSV100968973; called by muse, mutect2, varscan2
- PCDHB1 | c.2023C>A p.Q675K | Missense Mutation (SNP) | VAF 85/316 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV100128011; called by muse, mutect2, varscan2
- PCDHB13 | c.800C>T p.A267V | Missense Mutation (SNP) | VAF 78/225 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99506670; called by muse, mutect2, varscan2
- PCDHGA4 | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV53894994; called by muse, mutect2, varscan2
- PCDHGB3 | c.1547C>T p.A516V | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs781345070, COSV53933204; called by muse, mutect2
1,090 further variants in this file (612 protein-altering or splice-affecting, 440 silent, 38 other) are not listed here.
